Somatic mutation profile of tumor specimen TCGA-AX-A05Z-01A (aliquot TCGA-AX-A05Z-01A-11W-A027-09) from TCGA case TCGA-AX-A05Z, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 37.0 years (13,529 days).
Specimen TCGA-AX-A05Z-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2e9f8778-97f5-454e-ab3b-8199af61f0de.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AX-A05Z-10A (Blood Derived Normal), aliquot TCGA-AX-A05Z-10A-01W-A027-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c2a56983-ac98-4450-a7bc-e578f3bb7cb6

The open-access MAF lists 8,123 somatic variants for this specimen: 6,618 protein-altering or splice-affecting, 1,301 silent, 204 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5,426, Silent 1,301, Nonsense Mutation 1,012, Splice Site 92, Intron 88, RNA 62, Splice Region 42, Frame Shift Ins 20, 3'UTR 19, Nonstop Mutation 16, 5'Flank 13, 3'Flank 11.

Variants (750 of 8,123; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.4610C>T p.T1537M | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs62642575, CM003385; ClinVar: uncertain significance / pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.724G>T p.E242* | Nonsense Mutation (SNP) | VAF 65/219 reads (30%) | catalogued as rs72650697, CM073953, COSV52741670, COSV99227993; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC9 | c.3460C>T p.R1154W | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.981); catalogued as rs387907208, CM124860, COSV53963892; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ALDH1A3 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs397514652, CM132959, COSV60900963; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ASPM | c.4732C>T p.R1578* | Nonsense Mutation (SNP) | VAF 50/171 reads (29%) | catalogued as rs753406334, COSV54125634; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 42/146 reads (29%) | hotspot (GDC flag); catalogued as rs772821016, CM030188, CS991299, COSV53725394; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ATM | c.7792C>T p.R2598* | Nonsense Mutation (SNP) | VAF 28/94 reads (30%) | catalogued as rs138941496, CM960105, COSV53725297, COSV99588934; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BRCA2 | c.1528G>T p.E510* | Nonsense Mutation (SNP) | VAF 76/249 reads (31%) | catalogued as rs80358438, CM110364, COSV66448948, COSV66461911; ClinVar: pathogenic; called by muse, varscan2
- BRCA2 | c.2689G>T p.E897* | Nonsense Mutation (SNP) | VAF 17/67 reads (25%) | catalogued as rs979372317, COSV66448966, COSV66451123, COSV66458736; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- BRD7 | c.1834C>T p.R612* | Nonsense Mutation (SNP) | VAF 33/106 reads (31%) | catalogued as rs796065051, COSV54264750; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- CDH1 | c.2164+1G>A p.X722_splice | Splice Site (SNP) | VAF 37/91 reads (41%) | hotspot (GDC flag); catalogued as COSV55738516, COSV99931700; called by muse, mutect2
- CERKL | c.1090C>T p.R364* (on ENST00000339098 / NM_001030311.2; = p.R338* on NM_201548.5) | Nonsense Mutation (SNP) | VAF 45/183 reads (25%) | catalogued as rs748394238, CM156178, COSV59203916; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.1753G>T p.E585* | Nonsense Mutation (SNP) | VAF 27/89 reads (30%) | catalogued as rs397508296, CM920165, COSV50040595, COSV99140566; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CFTR | c.2551C>T p.R851* | Nonsense Mutation (SNP) | VAF 19/62 reads (31%) | catalogued as rs121909012, CM910073, COSV99135243; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CHEK2 | c.952G>T p.E318* (on ENST00000382580 / NM_001005735.2; = p.E275* on NM_007194.4) | Nonsense Mutation (SNP) | VAF 34/104 reads (33%) | catalogued as rs749963436, CM110735, COSV60416545; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL17A1 | c.433C>T p.R145* | Nonsense Mutation (SNP) | VAF 18/60 reads (30%) | catalogued as rs121912774, CM001969, COSV62225489; ClinVar: pathogenic; called by muse, mutect2, varscan2
- COL3A1 | c.976C>T p.R326* | Nonsense Mutation (SNP) | VAF 34/140 reads (24%) | catalogued as rs587779607, CM1412463, COSV58582838; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CRB1 | c.653-1G>T p.X218_splice | Splice Site (SNP) | VAF 22/257 reads (9%) | catalogued as rs760287363, COSV100958694; ClinVar: likely pathogenic; called by muse, mutect2
- EDARADD | c.454G>A p.E152K (on ENST00000334232 / NM_145861.4; = p.E142K on NM_080738.4) | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs74315309, CM013622, COSV100512683; ClinVar: pathogenic; called by muse, mutect2, varscan2
- EZH2 | c.2218G>A p.E740K (on ENST00000460911 / NM_001203247.2; = p.E745K on NM_004456.5) | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT deleterious (0.02); PolyPhen benign (0.047); catalogued as rs397515548, CM1110546, COSV57447594, COSV57464742; ClinVar: pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.8521G>T p.E2841* | Nonsense Mutation (SNP) | VAF 27/116 reads (23%) | catalogued as rs587782948, CM118006, COSV57310584, COSV57313168; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.4567C>T p.R1523* | Nonsense Mutation (SNP) | VAF 16/56 reads (29%) | catalogued as rs397515812, CD077398, CM001687, COSV57310609; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.2227C>T p.R743C | Missense Mutation (SNP) | VAF 49/185 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.765); catalogued as rs794728188, COSV57310667; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FOXP1 | c.1630C>T p.R544* | Nonsense Mutation (SNP) | VAF 56/207 reads (27%) | catalogued as rs1559602356, COSV59534092, COSV59536060; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HPSE2 | c.1516C>T p.R506* | Nonsense Mutation (SNP) | VAF 97/346 reads (28%) | catalogued as rs267606866, CM103331, COSV65181961; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ITGB4 | c.1660C>T p.R554* | Nonsense Mutation (SNP) | VAF 16/87 reads (18%) | catalogued as rs121912462, CM981090, COSV52322436; ClinVar: pathogenic; called by muse, mutect2, varscan2
- KMT2C | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 77/282 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs1403418496, COSV51343575; called by muse, mutect2, varscan2
- KRIT1 | c.1267C>T p.R423* | Nonsense Mutation (SNP) | VAF 15/59 reads (25%) | catalogued as rs886039402, CM022620, COSV60667006; ClinVar: pathogenic; called by muse, varscan2
- MED12 | c.3063C>A p.F1021L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0.05); PolyPhen benign (0.341); catalogued as rs797045698, COSV61333259; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- MSH2 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 24/100 reads (24%) | catalogued as rs63750328, CM068371, CM1110883, COSV51876187; ClinVar: pathogenic; called by muse, varscan2
- MSH6 | c.2836G>T p.E946* | Nonsense Mutation (SNP) | VAF 82/287 reads (29%) | catalogued as rs1558666905, COSV52274084; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MTHFR | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs754980119, CM950818; ClinVar: pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 74/251 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs3218714, CM930504, COSV62516821; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NEXN | c.1175G>A p.R392Q | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.775); catalogued as rs971313210, COSV57358805; ClinVar: likely pathogenic; called by muse, mutect2
- NF1 | c.7348C>T p.R2450* (on ENST00000358273 / NM_001042492.3; = p.R2429* on NM_000267.3) | Nonsense Mutation (SNP) | VAF 30/133 reads (23%) | hotspot (GDC flag); catalogued as rs786202457, CD000998, CM000818, COSV62193225; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 47/224 reads (21%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.207); catalogued as rs397517202, CM126696, COSV55873252, COSV55911053, COSV55955422; ClinVar: pathogenic; called by muse, varscan2
- PIK3CB | c.962G>A p.R321Q | Missense Mutation (SNP) | VAF 63/196 reads (32%) | hotspot (GDC flag); SIFT tolerated (0.6); PolyPhen benign (0.011); catalogued as rs1451809865, COSV56683754; called by muse, varscan2
- PIK3R1 | c.1381C>T p.R461* (on ENST00000521381 / NM_181523.3; = p.R191* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 36/95 reads (38%) | catalogued as rs1057519838, COSV57125001; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- POLE | c.857C>G p.P286R | Missense Mutation (SNP) | VAF 9/41 reads (22%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519943, COSV57673247, COSV57678855; ClinVar: uncertain significance / likely pathogenic / drug response; called by muse, mutect2, varscan2
- PPM1D | c.1573G>T p.E525* | Nonsense Mutation (SNP) | VAF 79/221 reads (36%) | hotspot (GDC flag); catalogued as rs759850701, COSV59954557; called by muse, mutect2, varscan2
- PRPH2 | c.584G>A p.R195Q | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as rs121918567, CM032999, CM149326, COSV57836319; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389G>A p.R130Q | Missense Mutation (SNP) | VAF 110/331 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs121909229, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic / likely pathogenic; called by muse, varscan2
- PTPRD | c.1292C>T p.S431L | Missense Mutation (SNP) | VAF 61/239 reads (26%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen possibly damaging (0.523); catalogued as rs764400127, COSV61926988, COSV61964410; called by muse, mutect2, varscan2
- RAD50 | c.3277C>T p.R1093* | Nonsense Mutation (SNP) | VAF 142/422 reads (34%) | catalogued as rs121912628, CM092910, COSV54748338; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SLC4A1 | c.1030C>T p.R344* | Nonsense Mutation (SNP) | VAF 21/77 reads (27%) | catalogued as rs750930293, CM1212125, COSV52258614; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TNNT2 | c.824G>A p.R275Q (on ENST00000236918; = p.R272Q on NM_000364.4) | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT tolerated (0.14); PolyPhen benign (0.233); catalogued as rs730881125, COSV52660825; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- XPO1 | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 24/106 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520009, COSV68944533, COSV68945324; ClinVar: likely pathogenic; called by muse, varscan2
- ZNF649 | c.593G>T p.R198I | Missense Mutation (SNP) | VAF 94/355 reads (26%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.031); catalogued as rs373638440, COSV56814561; called by muse, mutect2, varscan2
- A1BG | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV54049989; called by muse, mutect2
- A2M | c.866A>C p.K289T | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.334); catalogued as COSV59383485; called by muse, mutect2, varscan2
- A2ML1 | c.2212C>T p.L738F | Missense Mutation (SNP) | VAF 30/452 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV100228796, COSV55291298; called by muse, mutect2
- A2ML1 | c.3481G>T p.D1161Y | Missense Mutation (SNP) | VAF 49/196 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV55286597; called by muse, mutect2, varscan2
- AAK1 | c.2632C>A p.L878I | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); catalogued as COSV68642051; called by muse, mutect2, varscan2
- AASS | c.1279-1G>A p.X427_splice | Splice Site (SNP) | VAF 7/110 reads (6%) | catalogued as COSV100741750; called by muse, mutect2
- ABCA1 | c.2471C>T p.S824L | Missense Mutation (SNP) | VAF 45/284 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.763); catalogued as rs551884479, CM1210656, COSV66064183; called by muse, mutect2, varscan2
- ABCA1 | c.389G>T p.R130I | Missense Mutation (SNP) | VAF 75/235 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as CM129647, COSV66057667; called by muse, mutect2, varscan2
- ABCA10 | c.4543G>T p.E1515* | Nonsense Mutation (SNP) | VAF 44/187 reads (24%) | catalogued as COSV52218845; called by muse, mutect2, varscan2
- ABCA10 | c.3285C>T p.L1095= | Splice Region (SNP) | VAF 37/163 reads (23%) | catalogued as rs772704349, COSV52218858; called by muse, mutect2, varscan2
- ABCA10 | c.1756A>G p.M586V | Missense Mutation (SNP) | VAF 78/241 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.188); catalogued as COSV52218868; called by muse, mutect2, varscan2
- ABCA12 | c.6639G>T p.K2213N (on ENST00000272895 / NM_173076.3; = p.K1895N on NM_015657.3) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV55950751, COSV55951788; called by muse, mutect2, varscan2
- ABCA12 | c.4734G>T p.K1578N (on ENST00000272895 / NM_173076.3; = p.K1260N on NM_015657.3) | Missense Mutation (SNP) | VAF 36/146 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55950772; called by muse, mutect2, varscan2
- ABCA12 | c.1444G>A p.E482K (on ENST00000272895 / NM_173076.3; = p.E164K on NM_015657.3) | Missense Mutation (SNP) | VAF 35/133 reads (26%) | SIFT tolerated (0.33); PolyPhen benign (0.035); catalogued as rs150321357; called by muse, mutect2, varscan2
- ABCA12 | c.693G>T p.Q231H | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV55950806; called by muse, mutect2, varscan2
- ABCA13 | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs573740053, COSV101329921, COSV70026109; called by muse, mutect2, varscan2
- ABCA13 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 141/449 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); catalogued as COSV101330199, COSV70026114; called by muse, varscan2
- ABCA13 | c.1983G>T p.E661D | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV70026121, COSV70028213; called by muse, mutect2, varscan2
- ABCA13 | c.4759G>T p.E1587* | Nonsense Mutation (SNP) | VAF 75/266 reads (28%) | catalogued as COSV70026130, COSV70027603; called by muse, mutect2, varscan2
- ABCA13 | c.5636G>A p.R1879Q | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs763421969, COSV70026133, COSV70042106; called by muse, mutect2, varscan2
- ABCA13 | c.6913G>T p.D2305Y | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs776363780, COSV71284067; called by muse, mutect2, varscan2
- ABCA13 | c.14343G>T p.R4781S | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); catalogued as COSV68943958, COSV68947244; called by muse, mutect2, varscan2
- ABCA3 | c.1651G>T p.D551Y | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs761783609, COSV57050065; called by muse, mutect2, varscan2
- ABCA4 | c.1384G>T p.D462Y | Missense Mutation (SNP) | VAF 176/630 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.092); catalogued as COSV64671442; called by muse, mutect2, varscan2
- ABCA4 | c.405C>A p.F135L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV64671448, COSV64678007; called by muse, mutect2, varscan2
- ABCA5 | c.930+2T>C p.X310_splice | Splice Site (SNP) | VAF 23/70 reads (33%) | catalogued as COSV67015914; called by muse, mutect2, varscan2
- ABCA5 | c.90G>T p.K30N | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.834); catalogued as COSV67015917; called by muse, varscan2
- ABCA9 | c.3560C>A p.S1187Y | Missense Mutation (SNP) | VAF 73/198 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60621269; called by muse, varscan2
- ABCB1 | c.2615G>T p.G872V | Missense Mutation (SNP) | VAF 64/506 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55946049; called by muse, mutect2, varscan2
- ABCB1 | c.2288G>T p.G763V | Missense Mutation (SNP) | VAF 56/208 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55946060, COSV55951829; called by muse, mutect2, varscan2
- ABCB1 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 30/135 reads (22%) | catalogued as rs1222604496, COSV55945529; called by muse, mutect2, varscan2
- ABCB11 | c.527A>C p.K176T | Missense Mutation (SNP) | VAF 12/214 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.784); catalogued as COSV55595819; called by muse, mutect2
- ABCB4 | c.288G>T p.V96= | Splice Region (SNP) | VAF 14/45 reads (31%) | catalogued as COSV55932553; called by muse, mutect2, varscan2
- ABCB5 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as rs368226947; called by muse, mutect2, varscan2
- ABCB5 | c.3080G>A p.R1027H (on ENST00000404938 / NM_001163941.2; = p.R582H on NM_178559.6) | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.329); catalogued as rs745749100, COSV51703658, COSV51718688; called by muse, varscan2
- ABCB6 | c.2036C>T p.T679I | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs766853225, COSV54693415; called by muse, mutect2, varscan2
- ABCB6 | c.1414G>A p.E472K | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772815355, COSV54693434; called by muse, mutect2, varscan2
- ABCC12 | c.954G>T p.E318D | Missense Mutation (SNP) | VAF 14/161 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV100252513; called by mutect2, varscan2
- ABCC12 | c.281G>A p.R94Q | Missense Mutation (SNP) | VAF 24/108 reads (22%) | SIFT tolerated (0.53); PolyPhen benign (0.001); catalogued as rs142478393; called by muse, mutect2, varscan2
- ABCC2 | c.412C>T p.L138F | Missense Mutation (SNP) | VAF 56/154 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.172); catalogued as COSV64970648, COSV64970740; called by muse, mutect2, varscan2
- ABCC2 | c.572C>A p.S191* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as COSV64970651; called by muse, mutect2, varscan2
- ABCC2 | c.912T>A p.D304E | Missense Mutation (SNP) | VAF 169/648 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.055); catalogued as COSV64970653; called by muse, mutect2, varscan2
- ABCC2 | c.1731A>C p.Q577H | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV64984817; called by muse, mutect2, varscan2
- ABCC8 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.227); catalogued as rs531684936, COSV56846952, COSV56857515; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABCC9 | c.2812C>T p.R938* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as rs1565735122, COSV53963915; called by muse, mutect2, varscan2
- ABCE1 | c.1788C>A p.F596L | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as COSV56846283; called by muse, mutect2, varscan2
- ABCG2 | c.1213C>A p.L405M | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.457); catalogued as rs1045489007, COSV52943743; called by muse, mutect2, varscan2
- ABCG2 | c.418T>G p.L140V | Missense Mutation (SNP) | VAF 66/370 reads (18%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.913); catalogued as rs1265942342, COSV52943773; called by muse, varscan2
- ABCG5 | c.1078G>T p.D360Y | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV53209371, COSV53209690; called by muse, mutect2, varscan2
- ABHD18 | c.958C>T p.R320C (on ENST00000398965 / NM_001039717.2; = p.R227C on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs141361679, COSV101180723; called by muse, mutect2
- ABHD5 | c.166C>T p.R56C | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1358271126, COSV50006309; called by muse, mutect2, varscan2
- ABHD5 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 30/389 reads (8%) | catalogued as COSV99185463; called by muse, mutect2
- ABI1 | c.1335G>T p.K445N | Missense Mutation (SNP) | VAF 28/88 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.15); catalogued as COSV61015312; called by muse, varscan2
- ABI3 | c.950A>G p.Y317C | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99865448; called by muse, mutect2
- ABI3BP | c.481C>T p.R161* | Nonsense Mutation (SNP) | VAF 31/106 reads (29%) | catalogued as rs1205460574, COSV52546855; called by muse, mutect2, varscan2
- ABI3BP | c.191G>A p.G64D | Missense Mutation (SNP) | VAF 14/238 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99426201; called by muse, mutect2
- ABLIM1 | c.970A>C p.M324L | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.515); catalogued as COSV53300979; called by muse, mutect2, varscan2
- ABLIM2 | c.791G>A p.R264Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.747); catalogued as rs771456940, COSV99589460; called by mutect2, varscan2
- ABLIM3 | c.1178G>A p.R393H | Missense Mutation (SNP) | VAF 29/98 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.046); catalogued as rs753998757, COSV58639677, COSV58650142; called by muse, varscan2
- AC013477.1 | c.2551G>T p.E851* | Nonsense Mutation (SNP) | VAF 22/71 reads (31%) | catalogued as COSV53653189; called by muse, mutect2, varscan2
- AC093827.5 | c.20G>T p.R7I | Missense Mutation (SNP) | VAF 40/194 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV55744738; called by muse, varscan2
- AC098582.1 | c.1404G>T p.E468D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as COSV52017996; called by muse, mutect2, varscan2
- AC098582.1 | c.2293A>C p.N765H | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.034); catalogued as COSV52018006; called by muse, mutect2, varscan2
- AC098582.1 | c.2917C>A p.L973I | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52018027, COSV52019574; called by muse, mutect2, varscan2
- AC100868.1 | c.1099G>T p.E367* | Nonsense Mutation (SNP) | VAF 18/81 reads (22%) | catalogued as COSV51838779, COSV99226191, COSV99226762; called by muse, mutect2, varscan2
- AC105001.2 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as COSV59108449; called by muse, mutect2, varscan2
- AC126283.2 | c.1435G>A p.E479K | Missense Mutation (SNP) | VAF 26/98 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67097947; called by muse, mutect2, varscan2
- ACACB | c.2932G>T p.E978* | Nonsense Mutation (SNP) | VAF 42/166 reads (25%) | catalogued as COSV58129350; called by muse, varscan2
- ACACB | c.6496+1G>C p.X2166_splice | Splice Site (SNP) | VAF 36/98 reads (37%) | catalogued as COSV58129365; called by muse, mutect2, varscan2
- ACAD8 | c.220C>T p.P74S | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55539295; called by muse, mutect2, varscan2
- ACADM | c.1226T>G p.L409R | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.084); catalogued as COSV63719860; called by muse, mutect2, varscan2
- ACADSB | c.328G>T p.E110* | Nonsense Mutation (SNP) | VAF 27/107 reads (25%) | catalogued as COSV62550349; called by muse, mutect2, varscan2
- ACAP2 | c.1010+1G>T p.X337_splice | Splice Site (SNP) | VAF 71/196 reads (36%) | catalogued as COSV58749662; called by muse, mutect2, varscan2
- ACAP2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 47/163 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1232089082, COSV58749670; called by muse, mutect2, varscan2
- ACBD6 | c.812C>A p.S271Y | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.259); catalogued as rs1186863071, COSV62571867; called by muse, varscan2
- ACBD6 | c.457G>T p.E153* | Nonsense Mutation (SNP) | VAF 78/246 reads (32%) | catalogued as COSV62571873; called by muse, varscan2
- ACBD7 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 107/396 reads (27%) | catalogued as rs1382163370, COSV62252310, COSV62252316; called by muse, mutect2, varscan2
- ACE2 | c.839C>A p.S280Y | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.865); catalogued as rs1451564530, COSV99382693; called by muse, mutect2
- ACIN1 | c.3952C>T p.R1318C | Missense Mutation (SNP) | VAF 71/189 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs754538392, COSV52973736; called by muse, mutect2, varscan2
- ACKR4 | c.210G>T p.K70N | Missense Mutation (SNP) | VAF 52/352 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as COSV51442190; called by muse, varscan2
- ACOT12 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 19/89 reads (21%) | catalogued as rs780095623, COSV56892749; called by muse, mutect2, varscan2
- ACOT8 | c.256C>T p.R86W | Missense Mutation (SNP) | VAF 14/32 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs747087835, COSV54168584; called by muse, mutect2, varscan2
- ACP3 | c.273A>C p.K91N | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0.006); catalogued as COSV60484751; called by muse, mutect2, varscan2
- ACP5 | c.219T>G p.F73L | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54535392; called by muse, mutect2, varscan2
- ACRV1 | c.770G>A p.R257Q | Missense Mutation (SNP) | VAF 146/483 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as rs768673984, COSV59754494; called by muse, mutect2, varscan2
- ACSBG2 | c.1332G>T p.K444N | Missense Mutation (SNP) | VAF 17/217 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV99397343; called by muse, mutect2
- ACSL1 | c.1736G>A p.R579Q | Missense Mutation (SNP) | VAF 150/580 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.382); catalogued as rs202112997, COSV55660942; called by muse, mutect2, varscan2
- ACSL1 | c.1024G>A p.G342R | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1157716865, COSV55660954; called by muse, mutect2, varscan2
- ACSL1 | c.31C>T p.R11* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs1361601006, COSV55660967; called by muse, mutect2, varscan2
- ACSL4 | c.1510G>T p.E504* (on ENST00000340800 / NM_022977.2; = p.E463* on NM_004458.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 20/212 reads (9%) | catalogued as COSV100538471; called by muse, mutect2
- ACSL4 | c.141A>C p.K47N (on ENST00000340800 / NM_022977.2; = p.K6N on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.889); catalogued as COSV100538472; called by muse, mutect2
- ACSL6 | c.1755A>C p.Q585H (on ENST00000379240; = p.Q610H on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/176 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57295028; called by muse, varscan2
- ACSL6 | c.1713G>T p.E571D (on ENST00000379240; = p.E596D on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57295059; called by muse, varscan2
- ACSM2B | c.116A>G p.E39G | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV61656978; called by muse, mutect2, varscan2
- ACSM3 | c.1025A>C p.K342T | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.038); catalogued as COSV55500143; called by muse, mutect2, varscan2
- ACSM5 | c.797T>C p.I266T | Missense Mutation (SNP) | VAF 23/483 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.367); catalogued as COSV100088736; called by muse, mutect2
- ACSM5 | c.1039G>T p.G347* | Nonsense Mutation (SNP) | VAF 33/137 reads (24%) | catalogued as COSV59369909; called by muse, mutect2, varscan2
- ACSM6 | c.714T>G p.Y238* | Nonsense Mutation (SNP) | VAF 86/253 reads (34%) | catalogued as COSV58977650; called by muse, mutect2, varscan2
- ACTBL2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.52); catalogued as rs769733989, COSV70661031; called by muse, mutect2, varscan2
- ACTL6A | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 53/219 reads (24%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.503); catalogued as COSV66998722; called by muse, mutect2, varscan2
- ACTL9 | c.1115C>A p.A372D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61004910; called by muse, mutect2, varscan2
- ACTN2 | c.1988G>T p.S663I | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (1); PolyPhen possibly damaging (0.789); catalogued as COSV63972551; called by muse, mutect2, varscan2
- ACTR6 | c.1012C>T p.R338* | Nonsense Mutation (SNP) | VAF 40/123 reads (33%) | catalogued as rs1253396208, COSV51841209; called by muse, mutect2, varscan2
- ACTRT2 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.11); PolyPhen benign (0.257); catalogued as COSV65758913, COSV65759003; called by muse, varscan2
- ACVR1C | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771611279, COSV54644145; called by muse, mutect2, varscan2
- ACVR2B | c.634G>T p.D212Y | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as COSV100754206; called by muse, mutect2, varscan2
- ADAD1 | c.257T>G p.F86C | Missense Mutation (SNP) | VAF 38/134 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV56641908; called by muse, varscan2
- ADAM17 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 111/503 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.404); catalogued as COSV60397756; called by muse, mutect2, varscan2
- ADAM2 | c.1132G>T p.D378Y | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV55859359; called by muse, mutect2, varscan2
- ADAM20 | c.2124T>G p.F708L | Missense Mutation (SNP) | VAF 107/357 reads (30%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV56454217; called by muse, mutect2, varscan2
- ADAM22 | c.1242C>A p.F414L | Missense Mutation (SNP) | VAF 15/207 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99716459; called by muse, mutect2
- ADAM22 | c.2166G>T p.K722N | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as COSV55970923, COSV55975136; called by muse, mutect2, varscan2
- ADAM28 | c.2176G>T p.E726* | Nonsense Mutation (SNP) | VAF 24/376 reads (6%) | catalogued as COSV99738401; called by muse, mutect2
- ADAM29 | c.521G>A p.R174Q | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs537404539, COSV63660881; called by muse, mutect2, varscan2
- ADAM29 | c.761A>C p.K254T | Missense Mutation (SNP) | VAF 76/220 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.678); catalogued as COSV63660890; called by muse, mutect2, varscan2
- ADAM7 | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 84/262 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs1333012683, COSV51535711; called by muse, mutect2, varscan2
- ADAM7 | c.766G>T p.D256Y | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs910236169, COSV51535730; called by muse, mutect2, varscan2
- ADAM7 | c.1629A>C p.E543D | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs746759074, COSV51535750; called by muse, mutect2, varscan2
- ADAM9 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.506); catalogued as rs1344174952, COSV65946589; called by muse, varscan2
- ADAMDEC1 | c.121C>T p.L41F | Missense Mutation (SNP) | VAF 47/147 reads (32%) | SIFT tolerated (0.72); PolyPhen benign (0.284); catalogued as COSV56474244; called by muse, mutect2, varscan2
- ADAMDEC1 | c.402G>T p.K134N | Missense Mutation (SNP) | VAF 22/82 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1401817128, COSV56474251; called by muse, mutect2, varscan2
- ADAMDEC1 | c.505G>T p.E169* | Nonsense Mutation (SNP) | VAF 52/262 reads (20%) | catalogued as COSV56474262; called by muse, mutect2, varscan2
- ADAMTS1 | c.2215C>A p.H739N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV53168919, COSV99536039; called by mutect2, varscan2
- ADAMTS10 | c.2281C>T p.P761S | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.02); catalogued as rs1314345152, COSV54352470; called by muse, mutect2, varscan2
- ADAMTS14 | c.910A>G p.I304V | Missense Mutation (SNP) | VAF 18/69 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as rs766128304, COSV64599997; called by muse, mutect2, varscan2
- ADAMTS16 | c.2478G>T p.E826D | Missense Mutation (SNP) | VAF 56/191 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56976773, COSV56980243; called by muse, mutect2, varscan2
- ADAMTS19 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 67/257 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.185); catalogued as COSV50739347; called by muse, mutect2, varscan2
- ADAMTS2 | c.2533G>A p.D845N | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs76488852, COSV99281325; called by muse, mutect2, varscan2
- ADAMTS20 | c.5366A>C p.E1789A | Missense Mutation (SNP) | VAF 11/195 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0.005); catalogued as COSV101239132; called by muse, mutect2
- ADAMTS20 | c.1985G>A p.G662E | Missense Mutation (SNP) | VAF 58/184 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs766523272, COSV67127632, COSV67133995; called by muse, mutect2, varscan2
- ADAMTS3 | c.3520G>T p.D1174Y | Missense Mutation (SNP) | VAF 42/172 reads (24%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.121); catalogued as COSV54386145; called by muse, mutect2, varscan2
- ADAMTS5 | c.2363G>A p.G788E | Missense Mutation (SNP) | VAF 14/239 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99537421; called by muse, mutect2
- ADAMTS5 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53176252; called by muse, mutect2, varscan2
- ADAMTS6 | c.1850G>A p.R617Q | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs542293343; called by mutect2, varscan2
- ADAMTS7 | c.723G>T p.E241D | Missense Mutation (SNP) | VAF 7/70 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.71); catalogued as COSV66306128; called by muse, mutect2, varscan2
- ADAMTS8 | c.2418C>A p.F806L | Missense Mutation (SNP) | VAF 85/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV57291685, COSV57297586; called by muse, mutect2, varscan2
- ADAMTS9 | c.3508G>A p.A1170T | Missense Mutation (SNP) | VAF 26/79 reads (33%) | SIFT tolerated (0.61); PolyPhen benign (0.001); catalogued as COSV55776076; called by muse, mutect2, varscan2
- ADCY1 | c.2047A>C p.I683L | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52030849; called by muse, mutect2, varscan2
- ADCY2 | c.1147C>T p.R383C | Missense Mutation (SNP) | VAF 65/168 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1444489998, COSV57859329; called by muse, mutect2, varscan2
- ADCY2 | c.2115G>T p.E705D | Missense Mutation (SNP) | VAF 53/230 reads (23%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV57860819; called by muse, mutect2, varscan2
- ADCY5 | c.3084G>T p.E1028D | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV59194897; called by muse, mutect2, varscan2
- ADCY6 | c.1945C>A p.L649M | Missense Mutation (SNP) | VAF 25/81 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV57166465; called by muse, mutect2, varscan2
- ADCY9 | c.1171G>A p.E391K | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.933); catalogued as COSV53572158; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.319G>A p.D107N | Missense Mutation (SNP) | VAF 45/193 reads (23%) | SIFT tolerated (0.69); PolyPhen benign (0.005); catalogued as COSV58441741; called by muse, mutect2, varscan2
- ADD3 | c.750T>G p.I250M | Missense Mutation (SNP) | VAF 80/220 reads (36%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.99); catalogued as COSV53320834; called by muse, varscan2
- ADD3 | c.865C>A p.L289M | Missense Mutation (SNP) | VAF 22/400 reads (6%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.922); catalogued as rs898391855, COSV99523320; called by muse, mutect2
- ADGRA3 | c.2557C>A p.Q853K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV51560610; called by muse, varscan2
- ADGRA3 | c.2543G>A p.R848Q | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs966886838, COSV51560619; called by muse, varscan2
- ADGRB3 | c.3448C>A p.L1150I | Missense Mutation (SNP) | VAF 50/282 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as COSV53236130; called by muse, varscan2
- ADGRB3 | c.4331A>C p.K1444T | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.738); catalogued as COSV53236141; called by muse, mutect2, varscan2
- ADGRE1 | c.1115C>A p.S372Y | Missense Mutation (SNP) | VAF 80/272 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51672708, COSV51674277; called by muse, varscan2
- ADGRE3 | c.1558T>G p.L520V | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV53728588; called by muse, mutect2, varscan2
- ADGRE3 | c.1274C>T p.A425V | Missense Mutation (SNP) | VAF 25/82 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0.241); catalogued as COSV53728256; called by muse, mutect2, varscan2
- ADGRF1 | c.197G>T p.R66I | Missense Mutation (SNP) | VAF 78/268 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as COSV64799595; called by muse, mutect2, varscan2
- ADGRF4 | c.252A>C p.Q84H | Missense Mutation (SNP) | VAF 31/149 reads (21%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV51950036; called by muse, mutect2, varscan2
- ADGRF4 | c.991G>T p.E331* | Nonsense Mutation (SNP) | VAF 28/93 reads (30%) | catalogued as COSV51950045, COSV51951782; called by muse, mutect2, varscan2
- ADGRF5 | c.3985G>T p.E1329* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV51930466; called by muse, mutect2, varscan2
- ADGRG2 | c.2441G>A p.R814Q (on ENST00000379869 / NM_001079858.3; = p.R811Q on NM_005756.4) | Missense Mutation (SNP) | VAF 81/203 reads (40%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.586); catalogued as rs184370776, COSV61337768, COSV61340199; called by muse, mutect2, varscan2
- ADGRG4 | c.3160C>A p.L1054I | Missense Mutation (SNP) | VAF 106/1334 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); catalogued as COSV99795167; called by muse, mutect2
- ADGRG4 | c.4438G>T p.V1480F | Missense Mutation (SNP) | VAF 207/508 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.218); catalogued as COSV54950679; called by muse, mutect2, varscan2
- ADGRG4 | c.5792C>A p.S1931Y | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.48); catalogued as COSV99795171; called by muse, mutect2
- ADGRG4 | c.5974C>A p.L1992I | Missense Mutation (SNP) | VAF 86/289 reads (30%) | SIFT tolerated (0.42); PolyPhen benign (0.033); catalogued as COSV54950689; called by muse, mutect2, varscan2
- ADGRG4 | c.9242G>T p.*3081Lext*9 | Nonstop Mutation (SNP) | VAF 53/150 reads (35%) | catalogued as COSV54950711; called by muse, mutect2, varscan2
- ADGRL2 | c.1400G>T p.R467I | Missense Mutation (SNP) | VAF 57/158 reads (36%) | SIFT tolerated (0.21); PolyPhen benign (0.1); catalogued as COSV54655136, COSV54656571; called by muse, mutect2, varscan2
- ADGRL2 | c.3607C>T p.P1203S | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.199); catalogued as COSV54655151; called by muse, mutect2, varscan2
- ADGRV1 | c.791G>T p.R264I | Missense Mutation (SNP) | VAF 40/184 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.534); catalogued as COSV67979450, COSV67987240; called by muse, mutect2, varscan2
- ADGRV1 | c.2753G>T p.R918I | Missense Mutation (SNP) | VAF 84/295 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV67979452; called by muse, varscan2
- ADGRV1 | c.6778C>T p.R2260* | Nonsense Mutation (SNP) | VAF 18/64 reads (28%) | catalogued as rs779821643, COSV67977499; called by muse, mutect2, varscan2
- ADGRV1 | c.10979C>A p.S3660* | Nonsense Mutation (SNP) | VAF 20/350 reads (6%) | catalogued as COSV101315748, COSV67986508; called by muse, mutect2
- ADGRV1 | c.12424C>T p.R4142W | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.642); catalogued as rs534226753, COSV67978187; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADGRV1 | c.12829C>T p.R4277* | Nonsense Mutation (SNP) | VAF 24/116 reads (21%) | catalogued as COSV67977934; called by muse, mutect2, varscan2
- ADGRV1 | c.13577C>A p.S4526Y | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.355); catalogued as rs1280697053, COSV67979460; called by muse, mutect2, varscan2
- ADGRV1 | c.15981C>A p.F5327L | Missense Mutation (SNP) | VAF 18/60 reads (30%) | SIFT tolerated (0.47); PolyPhen benign (0.294); catalogued as rs1233821213, COSV67979461; called by muse, varscan2
- ADH1B | c.578G>A p.G193D | Missense Mutation (SNP) | VAF 149/459 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.285); catalogued as COSV59295352; called by muse, mutect2, varscan2
- ADH6 | c.1017G>T p.E339D | Missense Mutation (SNP) | VAF 112/416 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV52955169; called by muse, mutect2, varscan2
- ADH6 | c.749C>T p.P250L | Missense Mutation (SNP) | VAF 51/881 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as COSV99422181; called by muse, mutect2
- ADH7 | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 81/267 reads (30%) | catalogued as rs533257508, COSV52919802; called by muse, mutect2, varscan2
- ADH7 | c.41G>A p.G14D | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99265179; called by muse, mutect2
- ADIPOR2 | c.1118G>A p.R373H | Missense Mutation (SNP) | VAF 74/195 reads (38%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.624); catalogued as rs754002919, COSV63945555; called by muse, mutect2, varscan2
- ADNP | c.1865C>T p.T622I | Missense Mutation (SNP) | VAF 73/239 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.944); catalogued as COSV62424576; called by muse, mutect2, varscan2
- ADPRH | c.625T>G p.S209A | Missense Mutation (SNP) | VAF 23/128 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.006); catalogued as COSV63694517; called by muse, mutect2, varscan2
- AEBP1 | c.1711C>A p.R571S | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV99788653; called by muse, mutect2, varscan2
- AFAP1L1 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as rs755876664, COSV57044011; called by muse, mutect2, varscan2
- AFF2 | c.134C>A p.S45Y | Missense Mutation (SNP) | VAF 19/318 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV100649690, COSV60654881; called by muse, mutect2
- AFF2 | c.1397+1G>T p.X466_splice | Splice Site (SNP) | VAF 51/138 reads (37%) | catalogued as COSV53978723; called by muse, mutect2, varscan2
- AFF2 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs200490489, COSV99663239; called by muse, mutect2
- AFG1L | c.440A>G p.D147G | Missense Mutation (SNP) | VAF 33/157 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768252712, COSV64554841; called by muse, mutect2, varscan2
- AFM | c.650C>A p.S217Y | Missense Mutation (SNP) | VAF 16/89 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV56919193; called by muse, mutect2, varscan2
- AFM | c.1055C>T p.A352V | Missense Mutation (SNP) | VAF 33/134 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.37); catalogued as rs151113361, COSV56919198, COSV99888811; called by muse, mutect2, varscan2
- AFP | c.697C>T p.R233* | Nonsense Mutation (SNP) | VAF 27/135 reads (20%) | catalogued as rs1005598459, COSV56924178; called by muse, mutect2, varscan2
- AFTPH | c.1160G>T p.S387I | Missense Mutation (SNP) | VAF 54/197 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV53216167; called by muse, mutect2, varscan2
- AFTPH | c.1795C>T p.R599* | Nonsense Mutation (SNP) | VAF 44/144 reads (31%) | catalogued as COSV53216188; called by muse, mutect2, varscan2
- AFTPH | c.2063C>T p.T688M | Missense Mutation (SNP) | VAF 77/380 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs781022622, COSV53216208; called by muse, mutect2, varscan2
- AGAP1 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.19); PolyPhen benign (0.416); catalogued as rs753271398, COSV100364225, COSV58318458; called by muse, mutect2, varscan2
- AGAP2 | c.1240G>A p.D414N (on ENST00000547588 / NM_001122772.2; = p.D78N on NM_014770.4) | Missense Mutation (SNP) | VAF 64/146 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0.023); catalogued as rs775376899, COSV57727070; called by muse, varscan2
- AGBL1 | c.903G>T p.E301D | Missense Mutation (SNP) | VAF 129/407 reads (32%) | SIFT tolerated (0.36); PolyPhen benign (0.046); catalogued as COSV66850232; called by muse, mutect2, varscan2
- AGBL1 | c.2564G>A p.C855Y | Missense Mutation (SNP) | VAF 97/354 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66850240; called by muse, mutect2, varscan2
- AGBL2 | c.945T>G p.D315E | Missense Mutation (SNP) | VAF 72/262 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as COSV54090349; called by muse, varscan2
- AGGF1 | c.1681G>T p.E561* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV57227576, COSV57228398; called by muse, mutect2, varscan2
- AGMO | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 41/185 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as rs769378096, COSV61105387, COSV61106804; called by muse, mutect2, varscan2
- AGO3 | c.1207C>T p.R403W | Missense Mutation (SNP) | VAF 25/80 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1466158162, COSV55791614; called by muse, mutect2, varscan2
- AGT | c.1110G>T p.K370N | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.25); PolyPhen benign (0.003); catalogued as COSV64183981, COSV64184605; called by muse, mutect2, varscan2
- AGTPBP1 | c.1537C>T p.P513S (on ENST00000357081 / NM_001330701.2; = p.P473S on NM_015239.2) | Missense Mutation (SNP) | VAF 39/99 reads (39%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as COSV61268963; called by muse, mutect2, varscan2
- AGTR1 | c.17C>A p.S6Y | Missense Mutation (SNP) | VAF 12/97 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.374); catalogued as COSV100837004; called by muse, mutect2, varscan2
- AGTR2 | c.464G>T p.R155I | Missense Mutation (SNP) | VAF 163/411 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV64156183; called by muse, mutect2, varscan2
- AGXT2 | c.1504C>T p.R502C | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs200627716; called by muse, mutect2, varscan2
- AHCTF1 | c.4723C>A p.L1575I (on ENST00000366508; = p.L1549I on NM_015446.5) | Missense Mutation (SNP) | VAF 21/76 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.037); catalogued as COSV58246441; called by muse, mutect2, varscan2
- AHCTF1 | c.143T>C p.L48P (on ENST00000366508; = p.L22P on NM_015446.5) | Missense Mutation (SNP) | VAF 25/85 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV58246451; called by muse, mutect2, varscan2
- AHCYL1 | c.883G>T p.E295* | Nonsense Mutation (SNP) | VAF 40/94 reads (43%) | catalogued as COSV63208225; called by muse, mutect2, varscan2
- AHCYL2 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750447678, COSV61485403; called by muse, mutect2, varscan2
- AHNAK | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 43/138 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs1211319203, COSV57205263; called by muse, mutect2, varscan2
- AHNAK2 | c.15970G>T p.E5324* | Nonsense Mutation (SNP) | VAF 12/31 reads (39%) | catalogued as COSV60909005; called by muse, mutect2, varscan2
- AHNAK2 | c.14090C>T p.S4697L | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.33); PolyPhen benign (0.415); catalogued as rs377637525; called by muse, varscan2
- AHNAK2 | c.2122G>A p.D708N | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs1322644675, COSV60909028; called by muse, mutect2, varscan2
- AHR | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 59/169 reads (35%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as rs544271397, COSV54121875; called by muse, mutect2, varscan2
- AHR | c.2099T>G p.F700C | Missense Mutation (SNP) | VAF 36/155 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.838); catalogued as COSV54121888; called by muse, mutect2, varscan2
- AHRR | c.190C>T p.L64F | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57083128; called by muse, mutect2, varscan2
- AHSG | c.1067C>A p.P356H | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.04); catalogued as COSV99889964; called by muse, mutect2
- AIDA | c.195A>C p.K65N | Missense Mutation (SNP) | VAF 59/340 reads (17%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.993); catalogued as COSV60663155; called by muse, mutect2, varscan2
- AIFM3 | c.1399G>A p.D467N | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs756414037, COSV53145550; called by muse, mutect2, varscan2
- AIM2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1412108671, COSV63698423; called by muse, mutect2, varscan2
- AK7 | c.1826G>A p.R609Q | Missense Mutation (SNP) | VAF 49/140 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.48); catalogued as rs758921408, COSV50869348, COSV50870311; called by muse, mutect2, varscan2
- AK9 | c.5269C>T p.R1757C | Missense Mutation (SNP) | VAF 6/63 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs775310575, COSV69851307; called by mutect2, varscan2
- AK9 | c.4838G>T p.R1613I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV69849365; called by muse, mutect2, varscan2
- AK9 | c.3319C>A p.L1107I | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.67); catalogued as rs779494275, COSV58138188, COSV58141295; called by muse, mutect2, varscan2
- AK9 | c.619G>A p.E207K | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.205); catalogued as COSV53419999; called by muse, mutect2, varscan2
- AKAP10 | c.1706C>T p.A569V | Missense Mutation (SNP) | VAF 31/93 reads (33%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs371370941, COSV56730732; called by muse, mutect2, varscan2
- AKAP11 | c.957C>A p.F319L | Missense Mutation (SNP) | VAF 14/227 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99213769; called by muse, mutect2
- AKAP11 | c.3716G>A p.R1239K | Missense Mutation (SNP) | VAF 57/189 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0.013); catalogued as COSV50293062, COSV99214108; called by muse, mutect2, varscan2
- AKAP11 | c.4286G>T p.R1429I | Missense Mutation (SNP) | VAF 44/203 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1308479533, COSV50293081; called by muse, mutect2, varscan2
- AKAP12 | c.241C>A p.L81I | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.677); catalogued as COSV53570679; called by muse, mutect2, varscan2
- AKAP12 | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 41/169 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.781); catalogued as COSV53570690; called by muse, mutect2, varscan2
- AKAP13 | c.3451G>T p.E1151* | Nonsense Mutation (SNP) | VAF 32/110 reads (29%) | catalogued as COSV63449867; called by muse, mutect2, varscan2
- AKAP13 | c.5169G>T p.E1723D (on ENST00000394518 / NM_007200.5; = p.E1727D on NM_006738.6) | Missense Mutation (SNP) | VAF 66/221 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.565); catalogued as rs767513056, COSV63449878; called by muse, mutect2, varscan2
- AKAP13 | c.6775T>G p.L2259V (on ENST00000394518 / NM_007200.5; = p.L2263V on NM_006738.6) | Missense Mutation (SNP) | VAF 55/178 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.21); catalogued as COSV63449889; called by muse, mutect2, varscan2
- AKAP3 | c.38G>T p.G13V | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as COSV99961996; called by muse, mutect2
- AKAP4 | c.703G>A p.E235K | Missense Mutation (SNP) | VAF 120/294 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.01); catalogued as rs147442985, COSV62073813; called by muse, mutect2, varscan2
- AKAP6 | c.237G>T p.M79I | Missense Mutation (SNP) | VAF 64/258 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV55206272; called by muse, mutect2, varscan2
- AKAP6 | c.3265G>T p.E1089* | Nonsense Mutation (SNP) | VAF 44/158 reads (28%) | catalogued as COSV55206281; called by muse, mutect2, varscan2
- AKAP6 | c.4238T>G p.F1413C | Missense Mutation (SNP) | VAF 60/188 reads (32%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.41); catalogued as COSV55206290; called by muse, mutect2, varscan2
- AKAP6 | c.4706A>C p.E1569A | Missense Mutation (SNP) | VAF 109/335 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.664); catalogued as COSV55206300; called by muse, mutect2, varscan2
- AKAP6 | c.5355T>G p.I1785M | Missense Mutation (SNP) | VAF 64/190 reads (34%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.486); catalogued as COSV55206321; called by muse, mutect2, varscan2
- AKAP9 | c.767A>G p.H256R | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV62339950; called by muse, mutect2, varscan2
- AKAP9 | c.1945C>T p.R649* | Nonsense Mutation (SNP) | VAF 48/205 reads (23%) | catalogued as rs779398715, COSV62339967; called by muse, mutect2, varscan2
- AKAP9 | c.3485A>C p.Q1162P | Missense Mutation (SNP) | VAF 46/155 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV100662259, COSV62350660; called by muse, mutect2, varscan2
- AKAP9 | c.4567G>A p.E1523K | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.847); catalogued as COSV62339980; called by muse, mutect2, varscan2
- AKAP9 | c.10546G>T p.E3516* (on ENST00000359028; = p.E3492* on NM_005751.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 21/332 reads (6%) | catalogued as COSV100662262; called by muse, mutect2
- AKNAD1 | c.1484C>A p.S495Y | Missense Mutation (SNP) | VAF 14/131 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.06); catalogued as COSV100645455; called by muse, mutect2, varscan2
- AKNAD1 | c.458C>A p.S153* | Nonsense Mutation (SNP) | VAF 14/188 reads (7%) | catalogued as rs1309255942, COSV100645460, COSV62196448; called by muse, mutect2
- AKT3 | c.1100G>A p.R367Q | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.03); catalogued as COSV55609365; called by muse, mutect2, varscan2
- AL592490.1 | c.2605G>T p.E869* | Nonsense Mutation (SNP) | VAF 21/80 reads (26%) | catalogued as COSV101308151, COSV69424774; called by muse, mutect2, varscan2
- ALDH16A1 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 57/199 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs370671753; called by muse, mutect2, varscan2
- ALDH1A1 | c.961C>T p.R321* | Nonsense Mutation (SNP) | VAF 42/221 reads (19%) | catalogued as COSV52789403; called by muse, mutect2, varscan2
- ALDH1A1 | c.467G>A p.R156K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.03); catalogued as COSV52789414; called by muse, mutect2, varscan2
- ALDH1A2 | c.397C>A p.L133M | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as rs1331946971, COSV51078466; called by muse, varscan2
- ALDH1L2 | c.2540G>A p.R847Q | Missense Mutation (SNP) | VAF 44/630 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.191); catalogued as rs1001186206, COSV51552607; called by muse, mutect2
- ALDH6A1 | c.1538C>A p.T513N | Missense Mutation (SNP) | VAF 40/171 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV63245880; called by muse, mutect2, varscan2
- ALDH9A1 | c.1270T>A p.L424I | Missense Mutation (SNP) | VAF 56/196 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as COSV61339163; called by muse, mutect2, varscan2
- ALDOA | c.952G>A p.A318T (on ENST00000642816 / NM_001243177.4; = p.A264T on NM_184041.5) | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as rs781198918, COSV57632104; called by muse, mutect2, varscan2
- ALG10 | c.502C>A p.L168I | Missense Mutation (SNP) | VAF 22/574 reads (4%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.734); catalogued as COSV99848058; called by muse, mutect2
- ALG10 | c.1246C>T p.R416C | Missense Mutation (SNP) | VAF 86/301 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762214045, COSV56791818; called by muse, mutect2, varscan2
- ALG11 | c.147G>T p.K49N | Missense Mutation (SNP) | VAF 50/187 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.022); catalogued as COSV73000580; called by muse, mutect2, varscan2
- ALG12 | c.1084G>A p.A362T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | PolyPhen benign (0.124); catalogued as COSV58206360; called by muse, mutect2, varscan2
- ALG2 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 9/104 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs1350412580, COSV53059855; ClinVar: uncertain significance; called by muse, mutect2
- ALG5 | c.727C>T p.R243* | Nonsense Mutation (SNP) | VAF 20/279 reads (7%) | catalogued as COSV99523597; called by muse, mutect2
- ALG8 | c.738C>A p.F246L | Missense Mutation (SNP) | VAF 31/109 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV55199336; called by muse, mutect2, varscan2
- ALK | c.2178G>T p.W726C | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV66558964, COSV66590626; called by muse, mutect2, varscan2
- ALKBH3 | c.12A>C p.K4N | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.839); catalogued as COSV57023180; called by muse, mutect2, varscan2
- ALMS1 | c.7117G>T p.A2373S | Missense Mutation (SNP) | VAF 10/133 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.612); catalogued as COSV100042032; called by muse, mutect2
- ALMS1 | c.8132T>G p.F2711C | Missense Mutation (SNP) | VAF 126/552 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); catalogued as COSV52503985; called by muse, mutect2, varscan2
- ALMS1 | c.8449T>G p.F2817V | Missense Mutation (SNP) | VAF 134/285 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV52503991, COSV52521401; called by muse, mutect2, varscan2
- ALOX12B | c.1989G>T p.E663D | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.009); catalogued as COSV59871365; called by muse, mutect2, varscan2
- ALOX15 | c.1241T>C p.F414S | Missense Mutation (SNP) | VAF 107/330 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV53396378; called by muse, mutect2, varscan2
- ALPK2 | c.5156G>T p.G1719V | Missense Mutation (SNP) | VAF 57/206 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV64490587; called by muse, mutect2, varscan2
- ALPK2 | c.628G>T p.E210* | Nonsense Mutation (SNP) | VAF 96/294 reads (33%) | catalogued as COSV64490598; called by muse, mutect2, varscan2
- AMBN | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.28); PolyPhen benign (0); catalogued as COSV59825360; called by muse, mutect2, varscan2
- AMBN | c.277G>T p.E93* | Nonsense Mutation (SNP) | VAF 36/116 reads (31%) | catalogued as COSV100534408, COSV59825365; called by muse, mutect2, varscan2
- AMDHD1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV57137880; called by muse, mutect2, varscan2
- AMDHD1 | c.754G>T p.D252Y | Missense Mutation (SNP) | VAF 38/155 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.549); catalogued as COSV57137894, COSV57138028; called by muse, mutect2, varscan2
- AMDHD1 | c.1177A>G p.I393V | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV57137906; called by muse, mutect2, varscan2
- AMER1 | c.1219G>T p.E407* | Nonsense Mutation (SNP) | VAF 10/168 reads (6%) | catalogued as COSV57660035; called by muse, mutect2
- AMIGO1 | c.1280C>A p.P427H | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.808); catalogued as COSV100881013; called by muse, varscan2
- AMPH | c.1535T>C p.I512T | Missense Mutation (SNP) | VAF 60/233 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV57734462; called by muse, mutect2, varscan2
- AMY2A | c.3G>T p.M1? | Translation Start Site (SNP) | VAF 16/314 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV101340627; called by muse, mutect2
- ANAPC1 | c.2705C>T p.A902V | Missense Mutation (SNP) | VAF 100/322 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as rs201447717; called by muse, varscan2
- ANAPC4 | c.2276A>T p.D759V | Missense Mutation (SNP) | VAF 18/360 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.218); catalogued as COSV59546788; called by muse, mutect2
- ANAPC7 | c.1400A>C p.K467T | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.847); catalogued as COSV101482852; called by muse, mutect2
- ANK1 | c.98G>T p.R33I | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.648); catalogued as COSV55874619, COSV99702878; called by muse, mutect2, varscan2
- ANK2 | c.290G>A p.G97E | Missense Mutation (SNP) | VAF 15/50 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52148536; called by muse, mutect2, varscan2
- ANK2 | c.5471C>A p.S1824Y | Missense Mutation (SNP) | VAF 144/520 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as COSV100000943; called by muse, mutect2
- ANK2 | c.5971C>T p.R1991W | Missense Mutation (SNP) | VAF 230/445 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1442984107, COSV52148543; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ANK3 | c.11269A>G p.N3757D | Missense Mutation (SNP) | VAF 22/338 reads (7%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); catalogued as COSV99779433; called by muse, mutect2
- ANK3 | c.8696C>T p.S2899F | Missense Mutation (SNP) | VAF 14/167 reads (8%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV55045136; called by muse, mutect2
- ANK3 | c.7805T>G p.L2602R | Missense Mutation (SNP) | VAF 33/227 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV55046679; called by muse, mutect2, varscan2
- ANK3 | c.4733C>A p.S1578Y | Missense Mutation (SNP) | VAF 20/360 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.65); catalogued as COSV99779435; called by muse, mutect2
- ANKAR | c.1153G>T p.E385* | Nonsense Mutation (SNP) | VAF 34/82 reads (41%) | catalogued as COSV55609990; called by muse, varscan2
- ANKAR | c.4070G>A p.R1357Q | Missense Mutation (SNP) | VAF 82/353 reads (23%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as rs1376221117, COSV51461865; called by muse, mutect2, varscan2
- ANKEF1 | c.694G>A p.D232N | Missense Mutation (SNP) | VAF 58/211 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs771848473, COSV65692003; called by muse, mutect2, varscan2
- ANKH | c.1246G>A p.V416M | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as rs755062446, COSV52477629; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.972); catalogued as rs949524880, COSV51841395; called by muse, mutect2, varscan2
- ANKHD1-EIF4EBP3 | c.7429G>T p.G2477C | Missense Mutation (SNP) | VAF 41/160 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51841427; called by muse, mutect2, varscan2
- ANKMY1 | c.170G>A p.R57Q | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs768966375, COSV56030766; called by muse, mutect2, varscan2
- ANKMY2 | c.761G>A p.R254Q | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.888); catalogued as rs1163476120, COSV61011107; called by muse, mutect2, varscan2
- ANKMY2 | c.311C>T p.A104V | Missense Mutation (SNP) | VAF 81/281 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61011113; called by muse, mutect2, varscan2
- ANKRD1 | c.216G>T p.K72N | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.36); catalogued as COSV63310907; called by muse, mutect2, varscan2
- ANKRD11 | c.3151G>T p.E1051* | Nonsense Mutation (SNP) | VAF 67/279 reads (24%) | catalogued as COSV56355939; called by muse, mutect2, varscan2
- ANKRD12 | c.985G>T p.E329* | Nonsense Mutation (SNP) | VAF 66/228 reads (29%) | catalogued as COSV50819847; called by muse, mutect2, varscan2
- ANKRD12 | c.1256C>A p.S419Y | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100041090, COSV50824056; called by muse, mutect2
- ANKRD12 | c.2100T>G p.F700L | Missense Mutation (SNP) | VAF 18/229 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100041093; called by muse, mutect2
- ANKRD12 | c.3898G>A p.E1300K | Missense Mutation (SNP) | VAF 25/336 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.566); catalogued as rs1339495856, COSV100041094; called by muse, mutect2
- ANKRD13C | c.725G>A p.R242Q | Missense Mutation (SNP) | VAF 28/114 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs1406275483, COSV52029334; called by muse, mutect2, varscan2
- ANKRD17 | c.6570G>T p.K2190N | Missense Mutation (SNP) | VAF 22/347 reads (6%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.051); catalogued as COSV58215279, COSV58225548; called by muse, mutect2
- ANKRD17 | c.5254C>T p.R1752W | Missense Mutation (SNP) | VAF 79/262 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs1367782921, COSV58216120; called by muse, mutect2, varscan2
- ANKRD17 | c.4898G>A p.R1633H | Missense Mutation (SNP) | VAF 99/485 reads (20%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs746356125, COSV58216132; called by muse, mutect2, varscan2
- ANKRD17 | c.3061G>T p.D1021Y | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV58216142; called by muse, mutect2, varscan2
- ANKRD17 | c.2684G>T p.R895I | Missense Mutation (SNP) | VAF 65/240 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen possibly damaging (0.497); catalogued as COSV58216151; called by muse, mutect2, varscan2
- ANKRD20A4P | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 9/16 reads (56%) | catalogued as COSV62003799; called by mutect2, varscan2
- ANKRD20A4P | c.1059G>T p.K353N | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as COSV62003805; called by muse, mutect2, varscan2
- ANKRD26 | c.5095G>T p.E1699* | Nonsense Mutation (SNP) | VAF 102/335 reads (30%) | catalogued as COSV65774301; called by muse, mutect2, varscan2
- ANKRD27 | c.2853G>T p.K951N | Missense Mutation (SNP) | VAF 10/103 reads (10%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); catalogued as COSV100042710; called by muse, varscan2
- ANKRD27 | c.205A>C p.N69H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as COSV60129270; called by muse, mutect2, varscan2
- ANKRD28 | c.55G>A p.G19R | Missense Mutation (SNP) | VAF 41/158 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.165); catalogued as rs768094206, COSV67517055; called by muse, mutect2, varscan2
- ANKRD30A | c.1112A>C p.K371T (on ENST00000611781; = p.K315T on NM_052997.2) | Missense Mutation (SNP) | VAF 76/212 reads (36%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV64605130; called by muse, varscan2
- ANKRD30A | c.1212G>T p.E404D (on ENST00000611781; = p.E348D on NM_052997.2) | Missense Mutation (SNP) | VAF 74/264 reads (28%) | SIFT tolerated (0.47); PolyPhen benign (0.217); catalogued as COSV64605137; called by muse, varscan2
- ANKRD30A | c.1768G>T p.E590* (on ENST00000611781; = p.E534* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 28/264 reads (11%) | catalogued as rs1219669225, COSV64605157; called by muse, mutect2
- ANKRD30A | c.2482G>T p.E828* (on ENST00000611781; = p.E772* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV64605164; called by mutect2, varscan2
- ANKRD30A | c.3421G>T p.E1141* (on ENST00000611781; = p.E1085* on NM_052997.2) | Nonsense Mutation (SNP) | VAF 134/529 reads (25%) | catalogued as COSV100654579, COSV64605169; called by muse, mutect2, varscan2
- ANKRD30A | c.3705G>T p.M1235I (on ENST00000611781; = p.M1179I on NM_052997.2) | Missense Mutation (SNP) | VAF 77/238 reads (32%) | SIFT tolerated (0.19); PolyPhen benign (0.278); catalogued as COSV64605174; called by muse, mutect2, varscan2
- ANKRD36B | c.1320A>C p.K440N | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.031); catalogued as COSV51530606; called by muse, mutect2, varscan2
- ANKRD44 | c.2197G>T p.D733Y | Missense Mutation (SNP) | VAF 53/162 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56550205; called by muse, mutect2, varscan2
- ANKRD44 | c.2014A>G p.T672A | Missense Mutation (SNP) | VAF 44/139 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56550224; called by muse, mutect2, varscan2
- ANKRD49 | c.190C>T p.R64* | Nonsense Mutation (SNP) | VAF 26/300 reads (9%) | catalogued as rs1179815180, COSV100119570; called by muse, mutect2
- ANKRD50 | c.2894T>G p.F965C | Missense Mutation (SNP) | VAF 58/233 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs1560817986, COSV72385129; called by muse, mutect2, varscan2
- ANKRD50 | c.2209C>T p.R737* | Nonsense Mutation (SNP) | VAF 66/192 reads (34%) | catalogued as COSV101538877, COSV72385130; called by muse, mutect2, varscan2
- ANKRD50 | c.829G>T p.E277* | Nonsense Mutation (SNP) | VAF 11/47 reads (23%) | catalogued as COSV72385133; called by muse, mutect2, varscan2
- ANKRD7 | c.716G>T p.R239I | Missense Mutation (SNP) | VAF 18/82 reads (22%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.879); catalogued as COSV54554039, COSV99501169; called by muse, mutect2, varscan2
- ANKS1B | c.3265C>T p.R1089W (on ENST00000547776 / NM_152788.4; = p.R255W on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/97 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1410929626, COSV59115659; called by muse, mutect2, varscan2
- ANKS6 | c.1621C>T p.R541* | Nonsense Mutation (SNP) | VAF 8/23 reads (35%) | catalogued as rs1306952839, COSV62049044; called by muse, mutect2, varscan2
- ANO2 | c.1156G>T p.A386S (on ENST00000356134 / NM_001278597.3; = p.A390S on NM_001278596.3) | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.06); PolyPhen benign (0.124); catalogued as COSV59009694; called by muse, varscan2
- ANO4 | c.2320C>A p.L774I (on ENST00000392977 / NM_001286615.2; = p.L739I on NM_178826.4) | Missense Mutation (SNP) | VAF 35/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54587294; called by muse, mutect2, varscan2
- ANO4 | c.2708C>T p.S903L (on ENST00000392977 / NM_001286615.2; = p.S868L on NM_178826.4) | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.257); catalogued as COSV54587306; called by muse, mutect2, varscan2
- ANO5 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as CM117900, COSV61082614; called by muse, mutect2, varscan2
- ANP32D | c.34C>T p.R12W | Missense Mutation (SNP) | VAF 110/374 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.014); catalogued as rs141807268; called by muse, mutect2, varscan2
- ANP32D | c.297A>C p.K99N | Missense Mutation (SNP) | VAF 101/430 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV56980156; called by muse, mutect2, varscan2
- ANPEP | c.1906G>A p.E636K | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.23); catalogued as rs774559825, COSV55589577; called by muse, mutect2, varscan2
- ANPEP | c.1819+1G>A p.X607_splice | Splice Site (SNP) | VAF 11/30 reads (37%) | catalogued as COSV55589585; called by muse, mutect2, varscan2
- ANTXR2 | c.958G>A p.A320T | Missense Mutation (SNP) | VAF 48/161 reads (30%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.677); catalogued as rs756324499, COSV56313262; called by muse, mutect2, varscan2
- ANXA10 | c.781C>A p.H261N | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen benign (0.315); catalogued as COSV63738200; called by muse, mutect2, varscan2
- AOAH | c.855C>A p.F285L | Missense Mutation (SNP) | VAF 48/142 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV51736404, COSV51741835; called by muse, varscan2
- AOAH | c.744C>A p.F248L | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV51736413, COSV99332448; called by muse, mutect2, varscan2
- AOX1 | c.3044C>A p.P1015H | Missense Mutation (SNP) | VAF 10/176 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.222); catalogued as COSV101021887; called by muse, mutect2
- AP1G1 | c.2378G>A p.R793Q | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV55486120; called by muse, mutect2, varscan2
- AP1G1 | c.137G>A p.R46Q | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV55485296; called by muse, mutect2, varscan2
- AP1G2 | c.1774G>A p.G592S | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as rs781477641, COSV55337536; called by muse, mutect2, varscan2
- AP3B1 | c.2734C>T p.R912* | Nonsense Mutation (SNP) | VAF 57/182 reads (31%) | catalogued as rs752519227, COSV54877147; called by muse, varscan2
- AP3B2 | c.1960C>T p.R654C | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs760853121, COSV55606048; called by muse, mutect2, varscan2
- AP4B1 | c.1358C>T p.A453V | Missense Mutation (SNP) | VAF 15/220 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.186); catalogued as rs1280825027, COSV99870719; called by muse, mutect2
- AP4E1 | c.911G>A p.R304Q | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs768086723, COSV55915344; called by muse, mutect2, varscan2
- AP4E1 | c.1059A>C p.K353N | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.996); catalogued as COSV99956507; called by muse, varscan2
- AP4E1 | c.2236A>C p.T746P | Missense Mutation (SNP) | VAF 52/177 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV55915357; called by muse, mutect2, varscan2
- AP4E1 | c.2495C>T p.S832L | Missense Mutation (SNP) | VAF 73/244 reads (30%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as rs144189610, COSV55915364; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AP4M1 | c.219C>A p.N73K | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.075); catalogued as COSV57994283, COSV57996434; called by mutect2, varscan2
- APAF1 | c.1132G>T p.D378Y (on ENST00000551964 / NM_181861.2; = p.D367Y on NM_001160.3) | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as COSV59662024; called by muse, mutect2, varscan2
- APAF1 | c.2473G>T p.D825Y (on ENST00000551964 / NM_181861.2; = p.D814Y on NM_013229.3) | Missense Mutation (SNP) | VAF 21/103 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100452458; called by muse, mutect2, varscan2
- APBA2 | c.616G>A p.G206S | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as rs574988993, COSV68789135; called by muse, mutect2, varscan2
- APBB1IP | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 35/108 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.012); catalogued as rs779560771, COSV63076096, COSV63076563; called by muse, mutect2, varscan2
- APBB2 | c.2272C>T p.P758S (on ENST00000295974 / NM_001166050.2; = p.P759S on NM_004307.2) | Missense Mutation (SNP) | VAF 96/349 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV55947920; called by muse, varscan2
- APC | c.406G>T p.E136* | Nonsense Mutation (SNP) | VAF 41/185 reads (22%) | catalogued as COSV57327935, COSV99965567; called by muse, mutect2, varscan2
- APC | c.2281G>T p.E761* | Nonsense Mutation (SNP) | VAF 45/143 reads (31%) | catalogued as COSV57321824; called by muse, mutect2, varscan2
- APC | c.4630G>T p.E1544* | Nonsense Mutation (SNP) | VAF 111/365 reads (30%) | catalogued as COSV57327947, COSV57331833, COSV57342321, COSV57357142; called by muse, mutect2, varscan2
- APC | c.5856G>T p.Q1952H | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.977); catalogued as COSV99967131; called by muse, mutect2
- APC | c.6077C>A p.S2026Y | Missense Mutation (SNP) | VAF 24/306 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57342873; called by muse, mutect2
- APC | c.6508C>A p.P2170T | Missense Mutation (SNP) | VAF 68/291 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV57327957; called by muse, varscan2
- APLP2 | c.2253G>T p.E751D | Missense Mutation (SNP) | VAF 15/273 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1277847633, COSV99599612; called by muse, mutect2
- APOB | c.13538T>G p.F4513C | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.153); catalogued as rs1231966626, COSV51925234; called by muse, mutect2, varscan2
- APOB | c.12698C>T p.S4233L | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.007); catalogued as rs377125320, COSV51925242; called by muse, mutect2, varscan2
- APOB | c.10775C>T p.S3592F | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.41); PolyPhen benign (0.085); catalogued as COSV51925255; called by muse, mutect2, varscan2
- APOB | c.10023C>A p.F3341L | Missense Mutation (SNP) | VAF 74/220 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV51925267; called by muse, mutect2, varscan2
- APOB | c.9752A>G p.Y3251C | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV51925282; called by muse, mutect2, varscan2
- APOB | c.8510C>T p.T2837M | Missense Mutation (SNP) | VAF 52/374 reads (14%) | SIFT tolerated (0.35); PolyPhen benign (0.043); catalogued as rs776427191, COSV51925294; called by muse, mutect2, varscan2
- APOBEC1 | c.637T>G p.C213G | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV57548352; called by muse, mutect2, varscan2
- APOBEC1 | c.223G>T p.D75Y | Missense Mutation (SNP) | VAF 31/97 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57548361, COSV57548677; called by muse, mutect2, varscan2
- APOBEC2 | c.166T>C p.F56L | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs982194237, COSV55142115; called by muse, mutect2, varscan2
- APOBEC3D | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | catalogued as rs765057107, COSV53325807; called by muse, mutect2, varscan2
- APOBEC3H | c.29G>A p.R10H | Missense Mutation (SNP) | VAF 42/134 reads (31%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.586); catalogued as rs372088508, COSV62379059; called by muse, mutect2, varscan2
- APOD | c.219G>T p.K73N | Missense Mutation (SNP) | VAF 28/101 reads (28%) | SIFT tolerated (0.57); PolyPhen benign (0.011); catalogued as COSV58401557; called by muse, mutect2, varscan2
- APOL3 | c.511C>T p.R171C (on ENST00000349314 / NM_145640.2; = p.R100C on NM_014349.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 51/149 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); catalogued as rs1229739274, COSV62579232; called by muse, mutect2, varscan2
- APOL4 | c.287A>G p.D96G (on ENST00000352371 / NM_145660.2; = p.D93G on NM_030643.4) | Missense Mutation (SNP) | VAF 39/180 reads (22%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.921); catalogued as COSV60654064; called by muse, mutect2, varscan2
- APP | c.1713C>A p.N571K | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT tolerated (0.7); PolyPhen benign (0.031); catalogued as COSV60994665; called by muse, mutect2, varscan2
- APP | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 11/157 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV60994141; called by muse, mutect2
- APP | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 39/173 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.921); catalogued as rs376138420, COSV61006586; called by muse, mutect2, varscan2
- ARAP2 | c.2736G>T p.E912D | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.306); catalogued as COSV58283236; called by muse, mutect2, varscan2
- ARAP2 | c.2546C>T p.T849I | Missense Mutation (SNP) | VAF 62/202 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV58283245, COSV58291044; called by muse, mutect2, varscan2
- ARAP2 | c.1646A>C p.Q549P | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.839); catalogued as COSV58283251; called by muse, mutect2, varscan2
- ARAP2 | c.965-1G>T p.X322_splice | Splice Site (SNP) | VAF 40/121 reads (33%) | catalogued as COSV58282395, COSV58291435; called by muse, mutect2, varscan2
- ARAP2 | c.373A>C p.K125Q | Missense Mutation (SNP) | VAF 20/172 reads (12%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV58283265; called by muse, mutect2, varscan2
- ARAP3 | c.2596C>A p.P866T | Missense Mutation (SNP) | VAF 44/204 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as rs1410001586, COSV53349052; called by muse, mutect2, varscan2
- ARFGEF1 | c.5522A>G p.E1841G | Missense Mutation (SNP) | VAF 39/140 reads (28%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.005); catalogued as COSV51580829; called by muse, mutect2, varscan2
- ARFGEF1 | c.3692G>T p.R1231I | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV51603347, COSV51606549; called by muse, mutect2, varscan2
- ARFGEF1 | c.2449C>A p.L817I | Missense Mutation (SNP) | VAF 53/235 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.386); catalogued as COSV51603357; called by muse, mutect2, varscan2
- ARFIP1 | c.812G>A p.R271H (on ENST00000353617 / NM_001287432.1; = p.R239H on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/137 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs972103124, COSV61883329; called by muse, mutect2, varscan2
- ARG2 | c.543T>G p.F181L | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.356); catalogued as COSV53619158; called by muse, varscan2
- ARHGAP1 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 4/19 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100357887; called by muse, mutect2
- ARHGAP10 | c.289C>A p.L97M | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.942); catalogued as COSV100331136; called by muse, mutect2
- ARHGAP10 | c.396G>T p.K132N | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs376938461, COSV60595503; called by muse, varscan2
- ARHGAP10 | c.610T>G p.F204V | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.164); catalogued as COSV60595511; called by muse, mutect2, varscan2
- ARHGAP15 | c.47C>A p.S16Y | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.188); catalogued as rs893060410, COSV54480784; called by muse, mutect2, varscan2
- ARHGAP15 | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 39/149 reads (26%) | catalogued as COSV54480793, COSV54514102; called by muse, mutect2, varscan2
- ARHGAP15 | c.556A>G p.N186D | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as COSV54480808; called by muse, mutect2, varscan2
- ARHGAP17 | c.939C>A p.F313L | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV51505250; called by muse, mutect2, varscan2
- ARHGAP17 | c.67G>T p.E23* | Nonsense Mutation (SNP) | VAF 21/108 reads (19%) | catalogued as COSV51505272; called by muse, mutect2, varscan2
- ARHGAP24 | c.212C>A p.S71Y | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV67837028; called by muse, mutect2
- ARHGAP24 | c.810C>A p.F270L (on ENST00000395184 / NM_001025616.3; = p.F177L on NM_031305.3) | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51987071; called by muse, mutect2, varscan2
- ARHGAP24 | c.1053G>T p.K351N (on ENST00000395184 / NM_001025616.3; = p.K258N on NM_031305.3) | Missense Mutation (SNP) | VAF 78/335 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.214); catalogued as COSV51987088; called by muse, mutect2, varscan2
- ARHGAP25 | c.700T>G p.S234A (on ENST00000409202 / NM_001007231.3; = p.S226A on NM_014882.3) | Missense Mutation (SNP) | VAF 76/249 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54899106; called by muse, mutect2, varscan2
- ARHGAP26 | c.1539-1G>A p.X513_splice | Splice Site (SNP) | VAF 115/402 reads (29%) | catalogued as COSV50824832; called by muse, varscan2
- ARHGAP29 | c.1774G>T p.E592* | Nonsense Mutation (SNP) | VAF 137/375 reads (37%) | catalogued as COSV53108982; called by muse, mutect2, varscan2
- ARHGAP30 | c.3214G>T p.E1072* (on ENST00000368013 / NM_001025598.2; = p.E861* on NM_181720.3) | Nonsense Mutation (SNP) | VAF 38/123 reads (31%) | catalogued as COSV63515050; called by mutect2, varscan2
- ARHGAP30 | c.2343G>T p.E781D | Missense Mutation (SNP) | VAF 136/476 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.009); catalogued as COSV63515060; called by muse, varscan2
- ARHGAP30 | c.2245G>T p.E749* | Nonsense Mutation (SNP) | VAF 316/522 reads (61%) | catalogued as COSV63515066; called by muse, varscan2
- ARHGAP31 | c.3506C>T p.A1169V | Missense Mutation (SNP) | VAF 62/183 reads (34%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV51789685; called by muse, mutect2, varscan2
- ARHGAP32 | c.4714G>A p.E1572K (on ENST00000310343 / NM_001378025.1; = p.E1223K on NM_014715.4) | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.009); catalogued as rs200206728, COSV59843905; called by muse, mutect2, varscan2
- ARHGAP35 | c.455A>G p.D152G | Missense Mutation (SNP) | VAF 37/105 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.558); catalogued as COSV68329449; called by muse, mutect2, varscan2
- ARHGAP36 | c.446G>A p.R149H | Missense Mutation (SNP) | VAF 66/133 reads (50%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.976); catalogued as rs146720933, COSV52264471; called by muse, mutect2, varscan2
- ARHGAP9 | c.338C>A p.S113Y | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV62721475; called by muse, mutect2, varscan2
- ARHGEF10L | c.3224A>T p.Q1075L | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.258); catalogued as COSV51428812; called by muse, mutect2, varscan2
- ARHGEF12 | c.950G>T p.R317I | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as COSV63102975, COSV63105108; called by muse, varscan2
- ARHGEF12 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63102980; called by muse, mutect2, varscan2
- ARHGEF12 | c.1960G>T p.E654* | Nonsense Mutation (SNP) | VAF 13/52 reads (25%) | catalogued as COSV100755274, COSV63102985; called by muse, mutect2, varscan2
- ARHGEF2 | c.191A>G p.E64G (on ENST00000361247 / NM_001162383.2; = p.E37G on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV58107159; called by muse, mutect2, varscan2
- ARHGEF26 | c.2113G>T p.D705Y | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62844234; called by muse, mutect2, varscan2
- ARHGEF35 | c.1098G>T p.E366D | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT tolerated (0.15); PolyPhen benign (0.041); catalogued as COSV65312428; called by muse, mutect2, varscan2
- ARHGEF38 | c.13G>T p.E5* | Nonsense Mutation (SNP) | VAF 20/111 reads (18%) | catalogued as COSV54441101; called by muse, mutect2, varscan2
- ARHGEF6 | c.175G>A p.D59N | Missense Mutation (SNP) | VAF 12/215 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV99166649; called by muse, mutect2
- ARHGEF7 | c.1003G>T p.E335* (on ENST00000375741 / NM_001113511.2; = p.E157* on NM_003899.5 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 30/93 reads (32%) | catalogued as COSV54539485, COSV54543633; called by muse, mutect2, varscan2
- ARID1A | c.2014G>T p.E672* | Nonsense Mutation (SNP) | VAF 63/311 reads (20%) | catalogued as COSV61372664; called by muse, mutect2, varscan2
- ARID2 | c.4198G>T p.D1400Y | Missense Mutation (SNP) | VAF 41/179 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV57597096, COSV57600910; called by muse, mutect2, varscan2
- ARID2 | c.5417A>T p.E1806V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57597104; called by muse, mutect2, varscan2
- ARID4B | c.2770C>T p.R924* | Nonsense Mutation (SNP) | VAF 95/363 reads (26%) | catalogued as COSV51599089; called by muse, mutect2, varscan2
- ARID5B | c.101G>T p.R34I | Missense Mutation (SNP) | VAF 14/180 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.265); catalogued as COSV54425484, COSV99690532; called by muse, mutect2
- ARID5B | c.1258A>G p.I420V | Missense Mutation (SNP) | VAF 177/622 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1187049639, COSV54415045, COSV54418868; called by muse, mutect2, varscan2
- ARID5B | c.3410C>A p.S1137Y | Missense Mutation (SNP) | VAF 18/267 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99689472; called by muse, mutect2
- ARL1 | c.185A>C p.K62T | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.1); PolyPhen benign (0.237); catalogued as COSV55369951; called by muse, mutect2, varscan2
- ARL15 | c.272A>G p.K91R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.526); catalogued as COSV72289010; called by muse, mutect2, varscan2
- ARL16 | c.225G>T p.Q75H | Missense Mutation (SNP) | VAF 5/51 reads (10%) | SIFT tolerated (0.22); PolyPhen benign (0.006); catalogued as COSV100230409; called by mutect2, varscan2
- ARL6IP5 | c.447G>T p.E149D | Missense Mutation (SNP) | VAF 30/95 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.748); catalogued as COSV56234419; called by muse, mutect2, varscan2
- ARL6IP6 | c.454+1G>A p.X152_splice | Splice Site (SNP) | VAF 11/35 reads (31%) | catalogued as COSV58442211; called by muse, mutect2, varscan2
- ARMC3 | c.758C>T p.A253V | Missense Mutation (SNP) | VAF 29/101 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as COSV53057816; called by muse, mutect2, varscan2
- ARMC3 | c.1582G>A p.E528K | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1389228963, COSV53057828; called by muse, mutect2, varscan2
- ARMC4 | c.2581G>A p.A861T | Missense Mutation (SNP) | VAF 52/152 reads (34%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.933); catalogued as rs372383392, COSV59457470; called by muse, varscan2
- ARMC4 | c.2516G>A p.G839E | Missense Mutation (SNP) | VAF 54/175 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59457492, COSV59469277; called by muse, varscan2
- ARMC4 | c.2040G>T p.K680N | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.188); catalogued as COSV59457517; called by muse, mutect2, varscan2
- ARMC4 | c.911A>G p.K304R | Missense Mutation (SNP) | VAF 14/236 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as COSV53468946, COSV99518489; called by muse, mutect2
- ARMC4 | c.577G>T p.E193* | Nonsense Mutation (SNP) | VAF 10/184 reads (5%) | catalogued as COSV53463568; called by muse, mutect2
- ARMCX1 | c.1143G>T p.W381C | Missense Mutation (SNP) | VAF 68/290 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.796); catalogued as COSV65704930; called by muse, mutect2, varscan2
- ARMCX5 | c.1402G>T p.E468* | Nonsense Mutation (SNP) | VAF 18/354 reads (5%) | catalogued as COSV99863368; called by muse, mutect2
- ARMCX5-GPRASP2 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 26/523 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV100771879; called by muse, mutect2
- ARMH4 | c.1589C>A p.P530H | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.986); catalogued as COSV50761932; called by muse, mutect2, varscan2
- ARMH4 | c.1468G>T p.D490Y | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.655); catalogued as COSV50761942; called by muse, mutect2, varscan2
- ARMS2 | c.195G>T p.M65I | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.027); catalogued as COSV101600724, COSV73306982; called by muse, mutect2, varscan2
- ARNT2 | c.1373C>T p.S458L | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as rs374632017; called by muse, mutect2, varscan2
- ARSG | c.1093G>A p.V365M | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.052); catalogued as rs185381597; called by muse, mutect2
- ARSK | c.895C>A p.Q299K | Missense Mutation (SNP) | VAF 21/348 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as COSV101187538; called by muse, mutect2
- ASAH2 | c.1799C>T p.P600L | Missense Mutation (SNP) | VAF 96/367 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1319705711; called by muse, varscan2
- ASAH2 | c.1480G>T p.E494* | Nonsense Mutation (SNP) | VAF 228/786 reads (29%) | catalogued as COSV100270223; called by muse, varscan2
- ASAH2 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 116/411 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs907585652; called by muse, mutect2, varscan2
- ASAP1 | c.1701G>C p.L567F | Missense Mutation (SNP) | VAF 29/120 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV63045013; called by muse, mutect2, varscan2
- ASAP1 | c.1545T>G p.F515L | Missense Mutation (SNP) | VAF 6/102 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV100727945; called by muse, mutect2
- ASAP1 | c.750C>A p.F250L | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as COSV100727089; called by muse, mutect2
- ASAP2 | c.1001T>G p.F334C | Missense Mutation (SNP) | VAF 26/92 reads (28%) | SIFT tolerated (0.42); PolyPhen possibly damaging (0.754); catalogued as COSV55627987; called by muse, mutect2, varscan2
- ASB1 | c.682A>G p.T228A | Missense Mutation (SNP) | VAF 12/53 reads (23%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV52826407; called by muse, mutect2, varscan2
- ASB11 | c.770G>T p.R257I | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV60354282, COSV60356455; called by muse, mutect2, varscan2
- ASB11 | c.175A>G p.I59V | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV60354415, COSV60354938; called by muse, mutect2, varscan2
- ASB12 | c.655C>T p.R219C | Missense Mutation (SNP) | VAF 37/99 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); catalogued as rs1485298213, COSV62856154; called by muse, mutect2, varscan2
- ASB15 | c.12T>G p.N4K | Missense Mutation (SNP) | VAF 70/282 reads (25%) | SIFT tolerated (0.68); PolyPhen benign (0.013); catalogued as COSV51924081; called by muse, mutect2, varscan2
- ASB15 | c.1636C>T p.R546* | Nonsense Mutation (SNP) | VAF 44/203 reads (22%) | catalogued as rs1237485684, COSV51923543; called by muse, varscan2
- ASB9 | c.741G>T p.Q247H | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.292); catalogued as COSV100995457; called by muse, mutect2, varscan2
- ASB9 | c.488A>C p.K163T | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.103); catalogued as COSV66852419; called by muse, mutect2
- ASCC3 | c.5307T>G p.Y1769* | Nonsense Mutation (SNP) | VAF 14/172 reads (8%) | catalogued as COSV100976404; called by muse, mutect2
- ASCC3 | c.407G>A p.R136Q | Missense Mutation (SNP) | VAF 38/142 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.357); catalogued as rs919581054, COSV100226137, COSV61225723; called by muse, mutect2
- ASH1L | c.2393A>C p.K798T | Missense Mutation (SNP) | VAF 108/460 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.815); catalogued as COSV64205891; called by muse, mutect2, varscan2
- ASH1L | c.1477G>T p.E493* | Nonsense Mutation (SNP) | VAF 67/216 reads (31%) | catalogued as COSV64205895; called by muse, mutect2, varscan2
- ASIC2 | c.1075C>A p.L359I | Missense Mutation (SNP) | VAF 120/468 reads (26%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV56756627, COSV56757795; called by muse, varscan2
- ASNSD1 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 52/150 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV53623017; called by muse, mutect2, varscan2
- ASPM | c.6383A>T p.K2128I | Missense Mutation (SNP) | VAF 92/385 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV54125625; called by muse, mutect2, varscan2
- ASPM | c.4495C>T p.R1499W | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756067585, COSV54125044; called by muse, mutect2, varscan2
- ASPM | c.4493T>G p.F1498C | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99660093; called by muse, mutect2
- ASPM | c.4136C>A p.S1379Y | Missense Mutation (SNP) | VAF 35/209 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54125644, COSV54130937; called by muse, mutect2, varscan2
- ASPM | c.3938G>T p.R1313I | Missense Mutation (SNP) | VAF 77/495 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.131); catalogued as COSV54125650; called by muse, mutect2, varscan2
- ASPN | c.32C>T p.A11V | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV65015936; called by muse, mutect2, varscan2
- ASTE1 | c.1883C>A p.S628* | Nonsense Mutation (SNP) | VAF 24/111 reads (22%) | catalogued as rs772872624; called by muse, mutect2, varscan2
- ASTN2 | c.2326G>T p.E776* (on ENST00000313400 / NM_001365069.1; = p.E725* on NM_014010.5) | Nonsense Mutation (SNP) | VAF 22/288 reads (8%) | catalogued as COSV100526444; called by muse, mutect2
- ASXL1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.069); catalogued as rs1259109293, COSV60103968; called by mutect2, varscan2
- ASXL2 | c.993C>A p.F331L | Missense Mutation (SNP) | VAF 45/227 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV55454364, COSV99712155; called by muse, mutect2, varscan2
- ASXL2 | c.97G>T p.E33* | Nonsense Mutation (SNP) | VAF 12/36 reads (33%) | catalogued as COSV55454380; called by muse, mutect2, varscan2
- ASXL3 | c.731C>T p.T244I | Missense Mutation (SNP) | VAF 11/41 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.921); catalogued as COSV52458714; called by muse, mutect2, varscan2
- ASXL3 | c.952G>T p.G318W | Missense Mutation (SNP) | VAF 35/303 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV52458726; called by muse, mutect2, varscan2
- ASXL3 | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 7/78 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.34); catalogued as COSV99324352; called by muse, mutect2
- ASXL3 | c.2747T>C p.F916S | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV52458751; called by muse, mutect2, varscan2
- ATAD1 | c.979G>T p.E327* | Nonsense Mutation (SNP) | VAF 15/66 reads (23%) | catalogued as COSV57755913; called by muse, mutect2, varscan2
- ATAD2 | c.3271G>T p.E1091* | Nonsense Mutation (SNP) | VAF 34/122 reads (28%) | catalogued as COSV54877902; called by muse, mutect2, varscan2
- ATAD2 | c.2657C>A p.S886* | Nonsense Mutation (SNP) | VAF 56/162 reads (35%) | catalogued as COSV54877918; called by muse, mutect2, varscan2
- ATAD2B | c.4008A>C p.E1336D | Missense Mutation (SNP) | VAF 112/402 reads (28%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as COSV53195648; called by muse, mutect2, varscan2
- ATAD2B | c.1699G>T p.E567* | Nonsense Mutation (SNP) | VAF 6/74 reads (8%) | catalogued as COSV53196452, COSV53198162; called by muse, mutect2
- ATF6 | c.614T>C p.I205T | Missense Mutation (SNP) | VAF 166/525 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV63406146; called by muse, mutect2, varscan2
- ATF7IP2 | c.273C>A p.F91L | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.013); catalogued as rs1361151528, COSV61092378, COSV61095454; called by muse, mutect2, varscan2
- ATG13 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 31/116 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as rs759630324, COSV56317809; called by muse, mutect2, varscan2
- ATG2B | c.1540T>G p.F514V | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.024); catalogued as COSV100737907; called by muse, mutect2
- ATG2B | c.1094G>A p.R365Q | Missense Mutation (SNP) | VAF 39/133 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.357); catalogued as rs778368919, COSV100737778, COSV63421927; called by muse, mutect2, varscan2
- ATG4C | c.232G>T p.E78* | Nonsense Mutation (SNP) | VAF 46/145 reads (32%) | catalogued as COSV58604062; called by muse, mutect2, varscan2
- ATL3 | c.748C>T p.R250* | Nonsense Mutation (SNP) | VAF 19/63 reads (30%) | catalogued as COSV60295353; called by muse, mutect2, varscan2
- ATMIN | c.518C>T p.S173L | Missense Mutation (SNP) | VAF 54/203 reads (27%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.978); catalogued as rs199541307, COSV55145212; called by muse, mutect2, varscan2
- ATP10A | c.2377C>T p.R793W | Missense Mutation (SNP) | VAF 34/49 reads (69%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs747360622, COSV63512971, COSV63522119; called by muse, mutect2, varscan2
- ATP10B | c.3910C>A p.L1304I | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT tolerated (0.58); PolyPhen benign (0.018); catalogued as COSV59144695; called by muse, mutect2, varscan2
- ATP10D | c.3399C>A p.F1133L | Missense Mutation (SNP) | VAF 159/714 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.62); catalogued as rs777425761, COSV56704494; called by muse, mutect2, varscan2
- ATP10D | c.4148T>G p.F1383C | Missense Mutation (SNP) | VAF 95/280 reads (34%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.088); catalogued as COSV56687202; called by muse, mutect2, varscan2
- ATP11B | c.1084G>A p.E362K | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as rs1218452517, COSV60026567; called by muse, mutect2, varscan2
- ATP11B | c.3172A>G p.N1058D | Missense Mutation (SNP) | VAF 44/147 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV60026580; called by muse, mutect2, varscan2
- ATP13A5 | c.1923G>T p.K641N | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT tolerated (0.42); PolyPhen benign (0.102); catalogued as rs928557187, COSV100665011; called by muse, mutect2
- ATP1A1 | c.518G>A p.R173Q | Missense Mutation (SNP) | VAF 10/145 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99814313; called by muse, mutect2
- ATP1A3 | c.2596C>T p.L866F (on ENST00000545399 / NM_001256214.2; = p.L853F on NM_152296.5) | Missense Mutation (SNP) | VAF 66/196 reads (34%) | SIFT tolerated (0.24); PolyPhen benign (0.02); catalogued as COSV57485518; called by muse, mutect2, varscan2
- ATP1A4 | c.296A>C p.K99T | Missense Mutation (SNP) | VAF 81/305 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV63625637; called by muse, mutect2, varscan2
- ATP1A4 | c.1602G>T p.E534D | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.023); catalogued as COSV63625642; called by muse, mutect2, varscan2
- ATP1B3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 40/169 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.876); catalogued as COSV53949078; called by muse, mutect2, varscan2
- ATP23 | c.595G>T p.E199* | Nonsense Mutation (SNP) | VAF 63/404 reads (16%) | catalogued as COSV55685539; called by muse, mutect2, varscan2
- ATP2B2 | c.2535C>A p.D845E (on ENST00000352432; = p.D811E on NM_001683.5) | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV100659930; called by muse, mutect2
- ATP2C1 | c.2068G>A p.E690K | Missense Mutation (SNP) | VAF 71/224 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); catalogued as rs905995238, CM154426, COSV60752853, COSV60762794; called by muse, mutect2, varscan2
- ATP4A | c.839G>A p.R280H | Missense Mutation (SNP) | VAF 62/177 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0.015); catalogued as rs764349733, COSV52866049; called by muse, mutect2, varscan2
- ATP5MC3 | c.191C>T p.A64V | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT tolerated (0.56); PolyPhen benign (0.139); catalogued as COSV52976117, COSV52977032; called by muse, mutect2, varscan2
- ATP6V1A | c.145G>A p.E49K | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.56); PolyPhen benign (0.009); catalogued as rs778431937, COSV56361174; called by muse, mutect2, varscan2
- ATP6V1A | c.1325G>A p.R442H | Missense Mutation (SNP) | VAF 52/233 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56361181; called by muse, mutect2, varscan2
- ATP6V1B2 | c.1468G>T p.E490* | Nonsense Mutation (SNP) | VAF 50/151 reads (33%) | catalogued as COSV52352834; called by muse, mutect2, varscan2
- ATP6V1C1 | c.473+1G>A p.X158_splice | Splice Site (SNP) | VAF 31/110 reads (28%) | catalogued as rs1248211676, COSV67777368, COSV67778038; called by muse, mutect2, varscan2
- ATP6V1G1 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV65013989; called by muse, mutect2
- ATP7B | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 37/127 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs749626601, COSV54435660; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ATP8A1 | c.3082C>A p.L1028M | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.418); catalogued as COSV52529658; called by muse, mutect2, varscan2
- ATP8A1 | c.976A>C p.K326Q | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV100045739; called by muse, mutect2
- ATP8A2 | c.1232G>T p.R411M | Missense Mutation (SNP) | VAF 65/283 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV54939389; called by muse, varscan2
- ATP8A2 | c.1993G>A p.E665K | Missense Mutation (SNP) | VAF 50/189 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs535509828, COSV54936164, COSV99680731; called by muse, mutect2, varscan2
- ATP8A2 | c.2326G>A p.E776K | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.615); catalogued as rs748812032, COSV54939414; called by muse, mutect2, varscan2
- ATP8B4 | c.2603G>A p.R868Q | Missense Mutation (SNP) | VAF 128/441 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs778511160, COSV52710199; called by muse, mutect2, varscan2
- ATP8B4 | c.1456G>T p.E486* | Nonsense Mutation (SNP) | VAF 81/356 reads (23%) | catalogued as COSV52710206; called by muse, mutect2, varscan2
- ATP9B | c.727-1G>A p.X243_splice | Splice Site (SNP) | VAF 57/225 reads (25%) | catalogued as COSV56946921; called by muse, mutect2, varscan2
- ATP9B | c.1962C>A p.F654L | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.516); catalogued as COSV56946929; called by muse, mutect2, varscan2
- ATPSCKMT | c.28G>T p.E10* | Nonsense Mutation (SNP) | VAF 10/110 reads (9%) | catalogued as COSV99725803; called by muse, mutect2
- ATR | c.6308A>C p.E2103A | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.164); catalogued as rs1017810017, COSV63384466; called by muse, mutect2, varscan2
- ATR | c.3541G>A p.G1181S | Missense Mutation (SNP) | VAF 40/152 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.817); catalogued as rs756014190, COSV63384469, COSV63393453; called by muse, mutect2, varscan2
- ATR | c.1377G>T p.K459N | Missense Mutation (SNP) | VAF 15/197 reads (8%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.001); catalogued as COSV100638033; called by muse, mutect2
- ATRN | c.2074G>T p.E692* | Nonsense Mutation (SNP) | VAF 40/171 reads (23%) | catalogued as COSV53524447; called by muse, mutect2, varscan2
- ATRN | c.3736C>T p.R1246C | Missense Mutation (SNP) | VAF 37/146 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.886); catalogued as rs767305834, COSV53524459; called by muse, mutect2, varscan2
- ATRN | c.3952C>T p.R1318* | Nonsense Mutation (SNP) | VAF 14/82 reads (17%) | catalogued as COSV53523748; called by muse, mutect2, varscan2
- ATRNL1 | c.3175G>A p.A1059T | Missense Mutation (SNP) | VAF 24/147 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV58075770; called by muse, mutect2, varscan2
- ATRNL1 | c.3711C>A p.F1237L | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.068); catalogued as COSV58075777, COSV58089235; called by muse, mutect2, varscan2
- ATRX | c.4148A>C p.D1383A | Missense Mutation (SNP) | VAF 93/204 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.604); catalogued as COSV64872272; called by muse, mutect2, varscan2
- ATRX | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 238/559 reads (43%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as COSV64872276, COSV64885845; called by muse, mutect2, varscan2
- ATRX | c.2365G>T p.D789Y | Missense Mutation (SNP) | VAF 21/418 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.915); catalogued as COSV100970531; called by muse, mutect2
- ATRX | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 45/215 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.359); catalogued as COSV64869280; called by muse, mutect2, varscan2
- ATXN10 | c.514A>T p.K172* | Nonsense Mutation (SNP) | VAF 103/326 reads (32%) | catalogued as COSV53293976; called by muse, mutect2, varscan2
- ATXN2 | c.962G>A p.R321H (on ENST00000550104; = p.R161H on NM_002973.4) | Missense Mutation (SNP) | VAF 8/99 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.916); catalogued as rs1051375712, COSV101112699; called by muse, mutect2
- AUTS2 | c.459A>C p.E153D | Missense Mutation (SNP) | VAF 108/330 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV61385736; called by muse, mutect2, varscan2
- AVPR1A | c.1211C>T p.S404L | Missense Mutation (SNP) | VAF 54/186 reads (29%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.758); catalogued as rs762419353, COSV54545753, COSV54546368; called by muse, mutect2, varscan2
- AXDND1 | c.69A>C p.K23N | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.346); catalogued as COSV62640197; called by muse, varscan2
- AXDND1 | c.796T>C p.F266L | Missense Mutation (SNP) | VAF 51/180 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100858322; called by muse, varscan2
- AXDND1 | c.994G>T p.E332* | Nonsense Mutation (SNP) | VAF 63/233 reads (27%) | catalogued as COSV62640204; called by muse, mutect2, varscan2
- AZI2 | c.207G>T p.L69F | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV99843574; called by muse, mutect2, varscan2
- AZIN1 | c.1163C>A p.S388Y | Missense Mutation (SNP) | VAF 86/260 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV61479308; called by muse, varscan2
- AZIN2 | c.409G>T p.E137* | Nonsense Mutation (SNP) | VAF 13/78 reads (17%) | catalogued as COSV99613220; called by muse, mutect2, varscan2
- B2M | c.199G>T p.E67* | Nonsense Mutation (SNP) | VAF 13/286 reads (5%) | catalogued as COSV62564724, COSV62566483; called by muse, mutect2
- B3GALT2 | c.978G>T p.K326N | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.93); catalogued as rs763779071, COSV66463869; called by muse, mutect2, varscan2
- B4GALNT1 | c.1435G>A p.V479I | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.61); catalogued as rs995397312, COSV57541526; called by muse, mutect2, varscan2
- B4GALNT2 | c.1031G>A p.R344Q | Missense Mutation (SNP) | VAF 116/382 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs756612045, COSV55924974; called by muse, mutect2, varscan2
- B4GALT7 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.325); catalogued as COSV50352699, COSV99218935; called by muse, mutect2, varscan2
- BAAT | c.728C>A p.S243Y | Missense Mutation (SNP) | VAF 68/206 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV52287437; called by muse, mutect2, varscan2
- BABAM2 | c.219C>A p.F73L | Missense Mutation (SNP) | VAF 204/678 reads (30%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as COSV100568286, COSV59617630; called by muse, mutect2, varscan2
- BABAM2 | c.851C>T p.T284I | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT tolerated (0.08); PolyPhen benign (0.011); catalogued as rs372205006; called by muse, mutect2, varscan2
- BAG1 | c.901T>G p.F301V | Missense Mutation (SNP) | VAF 32/170 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.89); catalogued as COSV65651490; called by muse, mutect2, varscan2
- BAIAP2L1 | c.966A>C p.E322D | Missense Mutation (SNP) | VAF 43/139 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.001); catalogued as COSV50054755; called by muse, mutect2, varscan2
- BAIAP2L1 | c.478G>T p.E160* | Nonsense Mutation (SNP) | VAF 19/332 reads (6%) | catalogued as COSV50055099, COSV50057286; called by muse, mutect2
- BARD1 | c.425C>A p.S142* | Nonsense Mutation (SNP) | VAF 56/223 reads (25%) | catalogued as COSV53609402; called by muse, mutect2, varscan2
- BAZ1A | c.2941G>T p.D981Y | Missense Mutation (SNP) | VAF 34/134 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62409192; called by muse, varscan2
- BAZ1B | c.3167G>A p.R1056H | Missense Mutation (SNP) | VAF 150/533 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV59989036; called by muse, varscan2
- BAZ1B | c.2362A>C p.N788H | Missense Mutation (SNP) | VAF 21/316 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100289686; called by muse, mutect2
- BAZ2A | c.1657C>T p.R553C | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.998); catalogued as rs759006748, COSV51632239; called by mutect2, varscan2
- BAZ2B | c.6128C>A p.S2043Y | Missense Mutation (SNP) | VAF 52/170 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as COSV58596452; called by muse, mutect2, varscan2
- BAZ2B | c.5783C>A p.S1928* | Nonsense Mutation (SNP) | VAF 71/296 reads (24%) | catalogued as COSV58596461, COSV58605145; called by muse, mutect2, varscan2
- BAZ2B | c.5389T>G p.L1797V | Missense Mutation (SNP) | VAF 62/238 reads (26%) | SIFT tolerated (0.26); PolyPhen benign (0.047); catalogued as COSV58596471; called by muse, mutect2, varscan2
- BBS4 | c.253G>T p.E85* | Nonsense Mutation (SNP) | VAF 30/162 reads (19%) | catalogued as CM1110493, COSV51436660; called by muse, mutect2, varscan2
- BBS9 | c.917G>A p.G306E | Missense Mutation (SNP) | VAF 31/124 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.739); catalogued as COSV54158208; called by muse, mutect2, varscan2
- BBS9 | c.1541G>A p.R514Q | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT tolerated (0.35); PolyPhen benign (0.052); catalogued as rs899716022, COSV54157337; called by muse, mutect2, varscan2
- BBS9 | c.1990G>T p.E664* (on ENST00000242067 / NM_001348036.1; = p.E624* on NM_014451.3 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 179/609 reads (29%) | catalogued as COSV54156361, COSV54158237; called by muse, mutect2, varscan2
- BBX | c.830C>T p.S277F | Missense Mutation (SNP) | VAF 9/147 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100361366, COSV104395461; called by muse, mutect2
- BBX | c.990A>C p.E330D | Missense Mutation (SNP) | VAF 71/277 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV57879857; called by muse, mutect2, varscan2
- BBX | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 106/347 reads (31%) | catalogued as COSV57879879; called by muse, mutect2, varscan2
- BCAM | c.1314G>T p.Q438H | Missense Mutation (SNP) | VAF 25/109 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.358); catalogued as COSV54300781; called by muse, mutect2, varscan2
- BCAR3 | c.1753C>A p.L585I | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99550619; called by muse, mutect2, varscan2
- BCAS1 | c.676G>T p.E226* | Nonsense Mutation (SNP) | VAF 104/420 reads (25%) | catalogued as COSV65084163; called by muse, mutect2, varscan2
- BCHE | c.275C>A p.S92Y | Missense Mutation (SNP) | VAF 36/126 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV52254062; called by muse, mutect2, varscan2
- BCL11A | c.463G>A p.A155T (on ENST00000335712 / NM_001365609.1; = p.A189T on NM_018014.4) | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV59625213; called by muse, mutect2, varscan2
- BCL7A | c.498G>T p.E166D | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.978); catalogued as COSV55846814; called by muse, mutect2, varscan2
- BCLAF1 | c.2249G>A p.R750Q | Missense Mutation (SNP) | VAF 58/182 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.106); catalogued as rs78267720; called by muse, mutect2, varscan2
- BCLAF3 | c.1888A>C p.I630L (on ENST00000379682 / NM_001367774.1; = p.I601L on NM_198279.3) | Missense Mutation (SNP) | VAF 18/425 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV100503267; called by muse, mutect2
- BCLAF3 | c.1070A>C p.K357T | Missense Mutation (SNP) | VAF 79/199 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.866); catalogued as COSV61413252; called by muse, mutect2, varscan2
- BCORL1 | c.2366G>A p.R789H | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs769770475, COSV54390631, COSV54398067; called by muse, mutect2, varscan2
- BDP1 | c.1420G>T p.E474* | Nonsense Mutation (SNP) | VAF 32/195 reads (16%) | catalogued as COSV62429204; called by muse, mutect2, varscan2
- BDP1 | c.3862G>A p.E1288K | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.007); catalogued as COSV62429210; called by muse, mutect2, varscan2
- BDP1 | c.7538C>A p.S2513* | Nonsense Mutation (SNP) | VAF 40/158 reads (25%) | catalogued as COSV62429217; called by muse, mutect2, varscan2
- BET1 | c.202G>A p.D68N | Missense Mutation (SNP) | VAF 28/84 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.257); catalogued as COSV55992639; called by muse, mutect2, varscan2
- BFSP1 | c.1609A>C p.I537L | Missense Mutation (SNP) | VAF 33/136 reads (24%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100925376, COSV64899487; called by muse, mutect2, varscan2
- BFSP1 | c.736-1G>T p.X246_splice | Splice Site (SNP) | VAF 18/68 reads (26%) | catalogued as COSV64899492; called by muse, mutect2, varscan2
- BHLHE40 | c.332T>C p.I111T | Missense Mutation (SNP) | VAF 90/361 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.019); catalogued as rs763465378, COSV56574730; called by muse, mutect2, varscan2
- BICRAL | c.2619G>T p.M873I | Missense Mutation (SNP) | VAF 34/99 reads (34%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV58403741; called by muse, mutect2, varscan2
- BIRC2 | c.1005C>A p.F335L | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.273); catalogued as COSV57160579; called by muse, mutect2, varscan2
- BIRC6 | c.1224G>T p.K408N | Missense Mutation (SNP) | VAF 102/334 reads (31%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.999); catalogued as COSV70196094; called by muse, mutect2, varscan2
- BIRC6 | c.1964A>C p.K655T | Missense Mutation (SNP) | VAF 28/138 reads (20%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.999); catalogued as COSV70196101; called by muse, mutect2, varscan2
- BIRC6 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV70196110; called by muse, mutect2, varscan2
- BIRC6 | c.3259G>A p.D1087N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); catalogued as COSV70196114; called by muse, mutect2, varscan2
- BIRC6 | c.4145G>A p.R1382Q | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.031); catalogued as rs777368785, COSV70196117; called by muse, mutect2, varscan2
- BIRC6 | c.10294A>C p.I3432L | Missense Mutation (SNP) | VAF 76/328 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV70196121; called by muse, mutect2, varscan2
- BIRC6 | c.12493C>A p.L4165I | Missense Mutation (SNP) | VAF 86/401 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV70196123; called by muse, varscan2
- BIVM-ERCC5 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 58/140 reads (41%) | catalogued as COSV57278554; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2794C>T p.L932F | Missense Mutation (SNP) | VAF 13/99 reads (13%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.001); catalogued as COSV63244061; called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.4038C>A p.F1346L | Missense Mutation (SNP) | VAF 32/144 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.074); catalogued as COSV63244067; called by muse, mutect2, varscan2
- BMP2K | c.938A>T p.Y313F | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.47); catalogued as COSV58592539; called by muse, mutect2, varscan2
- BMP2K | c.2130G>T p.K710N | Missense Mutation (SNP) | VAF 43/164 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV55008724; called by muse, mutect2, varscan2
- BMP5 | c.79G>T p.G27* | Nonsense Mutation (SNP) | VAF 100/571 reads (18%) | catalogued as COSV63701273; called by muse, mutect2, varscan2
- BMPR1A | c.622G>T p.D208Y | Missense Mutation (SNP) | VAF 32/113 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV64405071; called by muse, mutect2, varscan2
- BMS1 | c.1171C>T p.R391* | Nonsense Mutation (SNP) | VAF 68/320 reads (21%) | catalogued as rs941209859, COSV65732977; called by muse, varscan2
- BMT2 | c.1078C>T p.R360* | Nonsense Mutation (SNP) | VAF 21/104 reads (20%) | catalogued as COSV51775023; called by muse, mutect2, varscan2
- BMT2 | c.695C>A p.S232Y | Missense Mutation (SNP) | VAF 24/81 reads (30%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV51775033; called by muse, mutect2, varscan2
- BNC1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 30/131 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61756657; called by muse, mutect2, varscan2
- BNC1 | c.357G>T p.L119F | Missense Mutation (SNP) | VAF 37/185 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as COSV61756660; called by muse, mutect2, varscan2
- BNIP3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.221); catalogued as rs769509016, COSV64043624; called by mutect2, varscan2
- BOD1L1 | c.4997C>A p.S1666Y | Missense Mutation (SNP) | VAF 94/472 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50007185; called by muse, varscan2
- BOD1L1 | c.3196T>G p.L1066V | Missense Mutation (SNP) | VAF 10/152 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.388); catalogued as COSV99239044; called by muse, mutect2
- BORA | c.486-1G>T p.X162_splice (on ENST00000613797; = p.X87_splice on NM_024808.5 and 1 other RefSeq transcript) | Splice Site (SNP) | VAF 21/70 reads (30%) | catalogued as COSV64694917; called by muse, mutect2, varscan2
- BPHL | c.845T>C p.F282S | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61318797; called by muse, mutect2, varscan2
- BPIFB4 | c.931C>A p.L311I | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100971491, COSV100971566; called by muse, mutect2, varscan2
- BPIFC | c.1282C>A p.L428I | Missense Mutation (SNP) | VAF 93/378 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.784); catalogued as COSV53277480; called by muse, varscan2
- BPIFC | c.803T>G p.F268C | Missense Mutation (SNP) | VAF 29/96 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV55911126; called by muse, mutect2, varscan2
- BPTF | c.3808G>T p.D1270Y | Missense Mutation (SNP) | VAF 23/130 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.656); catalogued as COSV58832306; called by muse, mutect2, varscan2
- BPTF | c.8331T>G p.I2777M | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV58831184, COSV58832321; called by muse, mutect2, varscan2
- BRAP | c.90A>C p.E30D | Missense Mutation (SNP) | VAF 67/247 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.142); catalogued as COSV58154425; called by muse, mutect2, varscan2
- BRCA2 | c.2275C>A p.L759I | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.003); catalogued as CD157745, COSV66448957, COSV66457401; called by muse, mutect2, varscan2
- BRCA2 | c.7426G>T p.E2476* | Nonsense Mutation (SNP) | VAF 23/113 reads (20%) | catalogued as COSV66448975; called by muse, mutect2, varscan2
- BRD7 | c.877G>T p.E293* | Nonsense Mutation (SNP) | VAF 80/349 reads (23%) | catalogued as COSV67158361; called by muse, mutect2, varscan2
- BRD8 | c.2464G>A p.E822K (on ENST00000254900 / NM_139199.2; = p.E895K on NM_006696.4) | Missense Mutation (SNP) | VAF 37/216 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.986); catalogued as COSV50145503; called by muse, mutect2, varscan2
- BRDT | c.574G>T p.V192L | Missense Mutation (SNP) | VAF 60/170 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV62863549, COSV62867622; called by muse, varscan2
- BRDT | c.844G>T p.E282* | Nonsense Mutation (SNP) | VAF 43/162 reads (27%) | catalogued as COSV62863553; called by muse, mutect2, varscan2
- BRDT | c.988G>T p.E330* | Nonsense Mutation (SNP) | VAF 7/80 reads (9%) | catalogued as COSV100746284; called by muse, mutect2
- BRDT | c.1108G>A p.E370K | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1254168076, COSV62863559; called by muse, mutect2, varscan2
- BRDT | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 60/187 reads (32%) | catalogued as COSV62863572, COSV62867237; called by muse, mutect2, varscan2
- BRINP1 | c.2098C>T p.R700W | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs541291613, COSV56291761, COSV99774028; called by muse, mutect2
- BRINP2 | c.2104C>T p.L702F | Missense Mutation (SNP) | VAF 59/277 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV64175866, COSV64180538; called by muse, mutect2, varscan2
- BRS3 | c.675C>A p.F225L | Missense Mutation (SNP) | VAF 45/136 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.267); catalogued as COSV65710719; called by muse, mutect2, varscan2
- BRWD1 | c.6748G>T p.E2250* | Nonsense Mutation (SNP) | VAF 61/183 reads (33%) | catalogued as COSV58999959; called by muse, mutect2, varscan2
- BRWD3 | c.4622C>A p.S1541* | Nonsense Mutation (SNP) | VAF 20/518 reads (4%) | catalogued as COSV64744601; called by muse, mutect2
- BRWD3 | c.4236C>A p.I1412= | Splice Region (SNP) | VAF 30/362 reads (8%) | catalogued as COSV100955926; called by muse, mutect2
- BRWD3 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 47/106 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV64744422; called by muse, mutect2, varscan2
- BSN | c.11523G>T p.Q3841H | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs746335182, COSV56513733; called by mutect2, varscan2
- BSX | c.350T>C p.F117S | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV58005128; called by muse, mutect2, varscan2
- BTAF1 | c.4556A>C p.D1519A | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99795204; called by muse, mutect2
- BTBD16 | c.192G>T p.K64N | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT tolerated (0.06); PolyPhen benign (0.382); catalogued as COSV99584672; called by muse, mutect2, varscan2
- BTBD9 | c.595G>A p.E199K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1416707237, COSV100021561; called by muse, mutect2
- BTD | c.392A>G p.D131G | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as rs772266503, COSV57728536; called by muse, mutect2, varscan2
- BTK | c.65C>A p.P22H | Missense Mutation (SNP) | VAF 58/251 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58117689; called by muse, varscan2
- BTN1A1 | c.1019G>T p.R340I | Missense Mutation (SNP) | VAF 103/353 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55066748; called by muse, mutect2, varscan2
- BTN3A2 | c.457G>A p.E153K | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs774256825, COSV62686837; called by muse, mutect2, varscan2
- BTNL2 | c.781G>T p.E261* | Nonsense Mutation (SNP) | VAF 21/76 reads (28%) | catalogued as COSV66630261; called by muse, mutect2, varscan2
- BTNL9 | c.937C>T p.R313W | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs146697971; called by muse, mutect2, varscan2
- BTRC | c.797C>A p.S266Y (on ENST00000370187 / NM_033637.4; = p.S230Y on NM_003939.5) | Missense Mutation (SNP) | VAF 96/277 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.852); catalogued as COSV64578883; called by muse, mutect2, varscan2
- BUD31 | c.218-1G>T p.X73_splice | Splice Site (SNP) | VAF 5/46 reads (11%) | catalogued as COSV52861260; called by muse, mutect2, varscan2
- BZW2 | c.871A>G p.T291A | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as COSV51754022; called by muse, mutect2, varscan2
- C10orf53 | c.308C>A p.S103Y | Missense Mutation (SNP) | VAF 160/449 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.017); catalogued as COSV65108597; called by muse, mutect2, varscan2
- C10orf53 | c.438T>G p.I146M | Missense Mutation (SNP) | VAF 86/349 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.071); catalogued as COSV100935034; called by muse, varscan2
- C10orf62 | c.540G>T p.K180N | Missense Mutation (SNP) | VAF 18/97 reads (19%) | SIFT tolerated (0.08); PolyPhen benign (0.048); catalogued as COSV65705069, COSV65705534; called by muse, mutect2, varscan2
- C10orf71 | c.1959T>A p.D653E | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV60505283; called by muse, mutect2, varscan2
- C10orf88 | c.910C>T p.L304F | Missense Mutation (SNP) | VAF 82/264 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0.066); catalogued as COSV64403727; called by muse, mutect2, varscan2
- C10orf90 | c.8A>C p.K3T | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); catalogued as COSV52950188; called by muse, mutect2, varscan2
- C11orf65 | c.694G>T p.E232* | Nonsense Mutation (SNP) | VAF 58/184 reads (32%) | catalogued as COSV67596900; called by muse, mutect2, varscan2
- C11orf65 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 24/177 reads (14%) | catalogued as COSV67596905; called by muse, mutect2, varscan2
- C12orf4 | c.1036T>G p.F346V | Missense Mutation (SNP) | VAF 52/221 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54205858; called by muse, mutect2, varscan2
- C12orf42 | c.272G>T p.R91M | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.813); catalogued as COSV59379525, COSV59381259; called by muse, mutect2, varscan2
- C12orf56 | c.1327C>A p.L443I (on ENST00000543942 / NM_001170633.2; = p.L283I on NM_001099676.3) | Missense Mutation (SNP) | VAF 11/124 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV100399251; called by muse, mutect2
- C12orf56 | c.1181A>G p.N394S (on ENST00000543942 / NM_001170633.2; = p.N234S on NM_001099676.3) | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.005); catalogued as rs867713051, COSV61485513; called by muse, mutect2, varscan2
- C12orf56 | c.286G>T p.D96Y | Missense Mutation (SNP) | VAF 29/138 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); catalogued as COSV61485519; called by muse, mutect2, varscan2
- C14orf28 | c.889C>A p.L297I | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.899); catalogued as COSV57332911; called by muse, mutect2, varscan2
- C14orf39 | c.865A>C p.K289Q | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT tolerated (0.34); PolyPhen benign (0.277); catalogued as COSV58779904; called by muse, varscan2
- C17orf80 | c.230G>T p.R77I | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99277973; called by muse, mutect2
- C1GALT1C1 | c.582G>T p.M194I | Missense Mutation (SNP) | VAF 47/151 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV58973786; called by muse, mutect2, varscan2
- C1QTNF1 | c.768G>T p.E256D | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.36); PolyPhen benign (0.101); catalogued as COSV59260845; called by muse, mutect2, varscan2
- C1QTNF9 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 24/140 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59656529; called by muse, varscan2
- C1orf100 | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as rs200395444, COSV57372060; called by muse, mutect2, varscan2
- C1orf141 | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.05); catalogued as COSV63992234; called by muse, mutect2
- C1orf141 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.173); catalogued as COSV63992240; called by muse, mutect2, varscan2
- C1orf158 | c.121G>T p.D41Y | Missense Mutation (SNP) | VAF 47/206 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV55346194; called by muse, mutect2, varscan2
- C1orf189 | c.229C>A p.L77M | Missense Mutation (SNP) | VAF 125/537 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63890817; called by muse, mutect2, varscan2
- C1orf87 | c.1589C>T p.S530L | Missense Mutation (SNP) | VAF 157/591 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as rs759893988, COSV64596223; called by muse, mutect2, varscan2
- C1orf87 | c.737C>A p.S246Y | Missense Mutation (SNP) | VAF 11/190 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.178); catalogued as COSV100967009; called by muse, mutect2
- C1orf94 | c.1117G>A p.A373T (on ENST00000488417 / NM_001134734.2; = p.A183T on NM_032884.5) | Missense Mutation (SNP) | VAF 43/171 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as rs781704626, COSV64913155; called by muse, mutect2, varscan2
- C1orf94 | c.1789A>C p.N597H (on ENST00000488417 / NM_001134734.2; = p.N407H on NM_032884.5) | Missense Mutation (SNP) | VAF 93/320 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.043); catalogued as COSV64913162; called by muse, mutect2, varscan2
- C20orf194 | c.691G>T p.D231Y | Missense Mutation (SNP) | VAF 49/154 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52692222; called by muse, mutect2, varscan2
- C20orf194 | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 15/335 reads (4%) | catalogued as COSV52692760, COSV52695653; called by muse, mutect2
7,373 further variants in this file (5,868 protein-altering or splice-affecting, 1,301 silent, 204 other) are not listed here.
